Somatic mutation profile of tumor specimen C3L-00006-01 (aliquot CPT0001460007) from CPTAC case C3L-00006, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Age at diagnosis: 64.9 years (23,700 days).
Specimen C3L-00006-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 99eb5a8e-6244-4456-aea4-dc337380ef7a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00006-31 (Blood Derived Normal), aliquot CPT0000120163; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b31b878f-87d3-4cf0-aa25-03c1a9fd7706

The open-access MAF lists 1,722 somatic variants for this specimen: 1,091 protein-altering or splice-affecting, 430 silent, 201 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 974, Silent 430, Intron 93, Nonsense Mutation 48, 3'UTR 34, Frame Shift Del 29, 5'UTR 26, RNA 25, 5'Flank 17, Splice Region 17, Frame Shift Ins 11, Splice Site 10.

Variants (750 of 1,722; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.5012del p.N1671Ifs*4 (on ENST00000272895 / NM_173076.3; = p.N1353Ifs*4 on NM_015657.3) | Frame Shift Del (DEL) | VAF 133/368 reads (36%) | catalogued as rs387906285, CD051281; ClinVar: pathogenic; called by mutect2, varscan2
- APC | c.694C>T p.R232* | Nonsense Mutation (SNP) | VAF 119/317 reads (38%) | hotspot (GDC flag); catalogued as rs397515734, CM920029, COSV57320753; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4666dup p.T1556Nfs*3 | Frame Shift Ins (INS) | VAF 133/387 reads (34%) | catalogued as rs587783031, COSV57351096; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- ATP1A2 | c.1127C>T p.T376M | Missense Mutation (SNP) | VAF 116/438 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121918620, CM053778, COSV100768285; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CARD11 | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 7/134 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1064795280, COSV62716575; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2
- DSG4 | c.865C>T p.R289* | Nonsense Mutation (SNP) | VAF 92/239 reads (38%) | catalogued as rs267606777, CM061705, COSV57389289; ClinVar: pathogenic; called by muse, varscan2
- ERBB3 | c.310G>A p.V104M | Missense Mutation (SNP) | VAF 127/303 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.64); catalogued as rs1057519893, COSV57246387, COSV57246465, COSV57253558; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1394G>A p.R465H (on ENST00000281708 / NM_001349798.2; = p.R385H on NM_018315.5) | Missense Mutation (SNP) | VAF 64/201 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FLNC | c.3557C>T p.A1186V | Missense Mutation (SNP) | VAF 52/132 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.809); catalogued as rs1114167361, CM1513881, COSV57951027; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- GNE | c.1009C>T p.R337* (on ENST00000396594 / NM_001128227.3; = p.R306* on NM_005476.7 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 202/545 reads (37%) | catalogued as rs1057516374, CM156982, COSV64952224; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- HNF1A | c.1424C>T p.P475L | Missense Mutation (SNP) | VAF 90/270 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.455); catalogued as rs193922580, CM092844; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- MAX | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 142/402 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52414939; called by muse, mutect2, varscan2
- MMAA | c.658G>A p.V220M | Missense Mutation (SNP) | VAF 76/189 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs150376474, COSV55582009; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MMUT | c.29dup p.L10Ffs*39 | Frame Shift Ins (INS) | VAF 19/156 reads (12%) | catalogued as rs1437477079; ClinVar: pathogenic; called by mutect2, varscan2
- NOTCH1 | c.743-1G>T p.X248_splice | Splice Site (SNP) | VAF 143/399 reads (36%) | catalogued as rs587777735, CS149814; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NPC1 | c.1301C>T p.P434L | Missense Mutation (SNP) | VAF 72/218 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs774333145, CM053352; ClinVar: likely pathogenic / uncertain significance; called by mutect2, varscan2
- NTRK1 | c.1945C>T p.R649W | Missense Mutation (SNP) | VAF 54/186 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369353892, CM990979, COSV100693131; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PAH | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 207/547 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs199475663, CM000544, CM981433, COSV61016854; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 48/160 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PPP2R1A | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 89/216 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519946, COSV59042187, COSV59042498; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 189/517 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 137/325 reads (42%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- SCN1B | c.254G>A p.R85H | Missense Mutation (SNP) | VAF 82/225 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.703); catalogued as rs16969925, CM071081; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TIMM50 | c.446C>T p.T149M | Missense Mutation (SNP) | VAF 122/341 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1244226820, COSV100067902; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 102/346 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TPP1 | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 64/230 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28940573, CM990368; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AAK1 | c.1775C>T p.A592V | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1214118045, COSV68647103; called by muse, mutect2, varscan2
- AANAT | c.391C>T p.R131W | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs970708682, COSV51684323; called by muse, mutect2, varscan2
- ABCA2 | c.2179C>T p.R727C (on ENST00000614293; = p.R697C on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 73/161 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs778475710; called by muse, mutect2, varscan2
- ABCA7 | c.3484G>A p.G1162R | Missense Mutation (SNP) | VAF 62/166 reads (37%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs753355079; called by muse, mutect2, varscan2
- ABCC11 | c.234G>A p.P78= | Splice Region (SNP) | VAF 22/41 reads (54%) | catalogued as rs530383890, COSV62321327; called by muse, mutect2, varscan2
- ABCD3 | c.1223G>A p.R408H | Missense Mutation (SNP) | VAF 50/556 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs759180503; called by muse, mutect2
- ABL1 | c.760G>A p.G254R | Missense Mutation (SNP) | VAF 72/182 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100584735, COSV59329201; called by muse, mutect2, varscan2
- AC097637.1 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 69/196 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1162856520, COSV59726161; called by muse, mutect2, varscan2
- ACACB | c.5434C>T p.R1812W | Missense Mutation (SNP) | VAF 159/385 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs757735587; called by muse, mutect2, varscan2
- ACAD10 | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 69/209 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as rs936482892, COSV58163358; called by muse, mutect2, varscan2
- ACOT9 | c.835C>T p.R279* | Nonsense Mutation (SNP) | VAF 82/203 reads (40%) | catalogued as rs199997116; called by muse, mutect2, varscan2
- ACTN4 | c.1847C>T p.P616L | Missense Mutation (SNP) | VAF 150/410 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.034); catalogued as rs763430701; called by muse, mutect2, varscan2
- ADAM22 | c.673C>T p.R225W | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs186904476; called by muse, mutect2, varscan2
- ADAM29 | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 49/99 reads (49%) | SIFT tolerated (0.42); PolyPhen benign (0.301); catalogued as rs750050614, COSV63661362; called by muse, mutect2, varscan2
- ADAMTSL2 | c.2017C>T p.R673W | Missense Mutation (SNP) | VAF 37/334 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1431912265; called by muse, mutect2, varscan2
- ADCK1 | c.770C>T p.T257M | Missense Mutation (SNP) | VAF 64/174 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs749434899; called by muse, mutect2, varscan2
- ADCY5 | c.1646C>T p.S549L | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as rs1459977492; called by muse, mutect2, varscan2
- ADCY9 | c.3034G>A p.V1012M | Missense Mutation (SNP) | VAF 101/233 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1415087301; called by muse, mutect2, varscan2
- ADGRA3 | c.1988G>A p.R663H | Missense Mutation (SNP) | VAF 46/140 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs767574676; called by muse, mutect2, varscan2
- ADGRB2 | c.4321C>T p.R1441C | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs774388490, COSV57071650; called by muse, mutect2, varscan2
- ADGRF5 | c.2378C>T p.T793M | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs751351835, COSV51929733; called by muse, mutect2, varscan2
- ADGRG5 | c.1220G>A p.R407Q | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.019); catalogued as rs142292696; called by muse, mutect2, varscan2
- ADGRV1 | c.16780C>T p.R5594C | Missense Mutation (SNP) | VAF 53/181 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as rs376062087; called by muse, mutect2, varscan2
- ADORA1 | c.478G>A p.G160S | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as rs367917658, COSV55141726; called by muse, mutect2, varscan2
- ADRA1B | c.579G>T p.K193N | Missense Mutation (SNP) | VAF 19/180 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.038); catalogued as COSV60701946; called by muse, mutect2, varscan2
- AGAP1 | c.1726C>T p.R576W (on ENST00000304032 / NM_001037131.3; = p.R523W on NM_014914.5) | Missense Mutation (SNP) | VAF 146/386 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58326271; called by muse, varscan2
- AGAP1 | c.1778C>T p.S593L (on ENST00000304032 / NM_001037131.3; = p.S540L on NM_014914.5) | Missense Mutation (SNP) | VAF 97/274 reads (35%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.974); catalogued as rs1380677446, COSV58325086; called by muse, varscan2
- AGBL1 | c.3083T>C p.L1028P | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs368320952; called by muse, mutect2, varscan2
- AGO1 | c.1436C>T p.A479V | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.072); catalogued as COSV64595452; called by muse, mutect2, varscan2
- AIFM1 | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 169/475 reads (36%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.289); catalogued as rs769299264; called by muse, mutect2, varscan2
- AIPL1 | c.325C>A p.Q109K | Missense Mutation (SNP) | VAF 113/272 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.158); catalogued as CM155836, COSV51508074; called by muse, mutect2, varscan2
- AK9 | c.5456C>T p.A1819V | Missense Mutation (SNP) | VAF 56/210 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs372465779, COSV69850596; called by muse, mutect2, varscan2
- AKAP12 | c.1880C>T p.S627L | Missense Mutation (SNP) | VAF 85/245 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as rs761711528, COSV99484400; called by muse, mutect2, varscan2
- ANGPTL4 | c.868T>G p.S290A | Missense Mutation (SNP) | VAF 120/346 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.033); catalogued as COSV56844358; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.7130G>A p.R2377Q | Missense Mutation (SNP) | VAF 67/157 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs747844917; called by muse, mutect2, varscan2
- ANKS6 | c.2275C>T p.R759W | Missense Mutation (SNP) | VAF 69/183 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.402); catalogued as rs756094728, COSV62049462; called by muse, mutect2, varscan2
- ANO8 | c.1162G>A p.V388M | Missense Mutation (SNP) | VAF 67/152 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.531); catalogued as rs760982994, COSV50198596; called by muse, mutect2, varscan2
- AP4B1 | c.1273G>A p.G425S | Missense Mutation (SNP) | VAF 121/338 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as rs777033290; called by muse, mutect2, varscan2
- APBA1 | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.17); catalogued as COSV55232380; called by muse, mutect2, varscan2
- APBB3 | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 152/443 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100020999, COSV60054137; called by muse, mutect2, varscan2
- APC | c.7646G>A p.R2549H | Missense Mutation (SNP) | VAF 78/206 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs199558585, COSV99965757; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APC | c.8386G>T p.D2796Y | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99967456; called by muse, mutect2, varscan2
- APCDD1L | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 125/405 reads (31%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as rs1360937357, COSV64485765; called by muse, mutect2, varscan2
- APOBEC1 | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 51/186 reads (27%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.991); catalogued as rs1206957347, COSV57550320; called by muse, mutect2, varscan2
- APPL2 | c.1180G>A p.A394T | Missense Mutation (SNP) | VAF 101/309 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs748958008; called by muse, mutect2, varscan2
- ARAP3 | c.1210C>T p.R404C | Missense Mutation (SNP) | VAF 101/287 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs1351256808; called by muse, mutect2, varscan2
- AREL1 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 73/180 reads (41%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.01); catalogued as COSV62666032; called by muse, mutect2, varscan2
- ARHGAP12 | c.2281C>T p.R761* | Nonsense Mutation (SNP) | VAF 47/120 reads (39%) | catalogued as rs750180294, COSV60961736; called by muse, mutect2, varscan2
- ARHGEF10 | c.2197G>A p.V733M (on ENST00000398564; = p.V708M on NM_014629.4) | Missense Mutation (SNP) | VAF 43/376 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.42); catalogued as rs769602938; called by muse, mutect2, varscan2
- ARMC6 | c.1174G>A p.A392T (on ENST00000392336; = p.A367T on NM_033415.4) | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs751161347, COSV54180304; called by muse, varscan2
- ARMH1 | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 93/224 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs866462582, COSV100679914; called by muse, varscan2
- ARMH2 | c.136del p.I46Sfs*20 | Frame Shift Del (DEL) | VAF 86/242 reads (36%) | catalogued as rs965020534; called by mutect2, varscan2
- ARRB2 | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.972); catalogued as rs772243126, COSV52616757; called by muse, mutect2, varscan2
- ASCC2 | c.2025C>T p.P675= | Splice Region (SNP) | VAF 54/207 reads (26%) | catalogued as rs770209491; called by muse, mutect2, varscan2
- ASIC4 | c.1357C>T p.R453* (on ENST00000347842 / NM_182847.3; = p.R472* on NM_018674.6) | Nonsense Mutation (SNP) | VAF 46/104 reads (44%) | catalogued as rs771596337, COSV61731572; called by muse, mutect2, varscan2
- ASIC5 | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 56/163 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as rs752632438, COSV73332561, COSV73332754; called by muse, mutect2, varscan2
- ASNSD1 | c.1388C>T p.A463V | Missense Mutation (SNP) | VAF 58/139 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs561528594; called by muse, mutect2, varscan2
- ASPHD2 | c.1060G>A p.A354T | Missense Mutation (SNP) | VAF 65/177 reads (37%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.995); catalogued as rs763956357, COSV53221015; called by muse, mutect2, varscan2
- ASXL3 | c.2060C>T p.P687L | Missense Mutation (SNP) | VAF 104/256 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV52467248; called by muse, mutect2, varscan2
- ATG9B | c.293del p.P98Qfs*8 | Frame Shift Del (DEL) | VAF 9/49 reads (18%) | catalogued as rs770350293; called by mutect2, pindel, varscan2
- ATL1 | c.967C>T p.R323W | Missense Mutation (SNP) | VAF 32/339 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1454910238, COSV63295919; called by muse, mutect2
- ATP10A | c.4175C>T p.A1392V | Missense Mutation (SNP) | VAF 15/252 reads (6%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs1403290397; called by muse, mutect2
- ATP6V1D | c.269C>T p.A90V | Missense Mutation (SNP) | VAF 51/167 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs754532623; called by muse, mutect2, varscan2
- ATP8B2 | c.1208C>T p.T403M (on ENST00000672630; = p.T370M on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 144/376 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.394); catalogued as rs1050193940, COSV59247342; called by muse, mutect2, varscan2
- AVPI1 | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 70/185 reads (38%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.966); catalogued as rs749235296; called by muse, mutect2, varscan2
- AVPR1B | c.208C>T p.H70Y | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.122); catalogued as rs782118712, COSV65638670; called by muse, mutect2, varscan2
- AXL | c.2110C>T p.R704C (on ENST00000301178 / NM_021913.5; = p.R695C on NM_001699.6) | Missense Mutation (SNP) | VAF 60/205 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781426924, COSV56563209; called by muse, mutect2, varscan2
- B2M | c.346+2T>C p.X116_splice | Splice Site (SNP) | VAF 13/325 reads (4%) | catalogued as COSV62565080, COSV62565694; called by muse, mutect2
- B3GALT1 | c.818G>A p.R273Q | Missense Mutation (SNP) | VAF 66/150 reads (44%) | SIFT tolerated (0.67); PolyPhen benign (0.035); catalogued as rs866876110, COSV59909329; called by muse, mutect2, varscan2
- BAG6 | c.1552G>A p.A518T | Missense Mutation (SNP) | VAF 104/340 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.145); catalogued as rs1356875376; called by muse, mutect2, varscan2
- BAG6 | c.1219G>A p.V407M | Missense Mutation (SNP) | VAF 67/195 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.186); catalogued as rs935551131; called by muse, mutect2, varscan2
- BARD1 | c.1805G>A p.S602N | Missense Mutation (SNP) | VAF 124/387 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as rs761883180, COSV53617188; called by muse, mutect2, varscan2
- BCL7B | c.593C>T p.T198M | Missense Mutation (SNP) | VAF 69/154 reads (45%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.353); catalogued as rs782026116; called by muse, mutect2, varscan2
- BCLAF1 | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 34/166 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs749571754, COSV62140896, COSV62145125; called by muse, mutect2, varscan2
- BEND2 | c.617T>C p.L206S | Missense Mutation (SNP) | VAF 9/297 reads (3%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs1292472208, COSV66215680; called by muse, mutect2
- BEST3 | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 18/320 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1466171439, COSV56994732; called by muse, mutect2
- BEST4 | c.151C>T p.R51W | Missense Mutation (SNP) | VAF 53/136 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs75504010; called by muse, mutect2, varscan2
- BHLHA15 | c.259C>T p.R87W | Missense Mutation (SNP) | VAF 137/368 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1386327511; called by muse, mutect2, varscan2
- BIN1 | c.1439C>T p.T480M (on ENST00000316724 / NM_001320642.1; = p.T341M on NM_004305.4) | Missense Mutation (SNP) | VAF 135/385 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.542); catalogued as rs780918654; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BMP6 | c.1186C>T p.R396W | Missense Mutation (SNP) | VAF 24/317 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs752583866, COSV99306290; called by muse, mutect2
- BRD4 | c.1528C>T p.R510W | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs144627512, COSV54589928; called by muse, mutect2, varscan2
- BRSK1 | c.1705C>T p.R569C | Missense Mutation (SNP) | VAF 68/176 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs745808194; called by muse, mutect2, varscan2
- BSN | c.2903C>T p.T968M | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1037255482, COSV99610219; called by muse, mutect2, varscan2
- BUD13 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs550124526; called by muse, mutect2, varscan2
- C17orf107 | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 72/199 reads (36%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.03); catalogued as rs1264809873; called by muse, mutect2, varscan2
- C19orf54 | c.448G>A p.V150I | Missense Mutation (SNP) | VAF 57/160 reads (36%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs142009558; called by muse, mutect2, varscan2
- C1QTNF8 | c.229G>A p.V77I | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.182); catalogued as rs759165911, COSV60518799; called by muse, mutect2, varscan2
- C1orf127 | c.1705G>A p.G569R | Missense Mutation (SNP) | VAF 47/98 reads (48%) | SIFT tolerated (0.39); PolyPhen benign (0.125); catalogued as rs143293968, COSV65436266; called by muse, mutect2, varscan2
- C5orf47 | c.100G>A p.G34S | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as rs1419947906; called by muse, mutect2, varscan2
- C6orf132 | c.3289G>A p.G1097R | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1248852340; called by muse, mutect2, varscan2
- C7 | c.40G>T p.G14* | Nonsense Mutation (SNP) | VAF 71/165 reads (43%) | catalogued as rs868082624; called by muse, mutect2, varscan2
- C7orf26 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 147/380 reads (39%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.997); catalogued as rs149671282, COSV60420057; called by muse, mutect2, varscan2
- CABP1 | c.764G>A p.R255H (on ENST00000316803 / NM_001033677.1; = p.R52H on NM_004276.5) | Missense Mutation (SNP) | VAF 90/246 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747880479, COSV56458162; called by muse, mutect2, varscan2
- CACNA1E | c.3526G>A p.V1176I | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.48); catalogued as rs1228218600, COSV62382262; called by muse, mutect2
- CACNA1I | c.4288G>A p.V1430M | Missense Mutation (SNP) | VAF 120/318 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60809804; called by muse, mutect2, varscan2
- CAPN1 | c.1729C>T p.H577Y | Missense Mutation (SNP) | VAF 111/311 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.179); catalogued as rs377272789; called by muse, mutect2, varscan2
- CARD10 | c.976C>T p.R326W | Missense Mutation (SNP) | VAF 55/126 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs1292631266, COSV52655740; called by muse, mutect2, varscan2
- CASTOR2 | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 29/300 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as rs1277735312; called by muse, mutect2, varscan2
- CASZ1 | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 112/263 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); catalogued as rs748111849, COSV100681433, COSV59733404; called by muse, mutect2, varscan2
- CAVIN1 | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 28/668 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.754); catalogued as rs1283817019, COSV63811330; called by muse, mutect2
- CCDC125 | c.92G>A p.G31D | Missense Mutation (SNP) | VAF 74/193 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765995374; called by muse, mutect2, varscan2
- CCDC170 | c.1914dup p.S639Ifs*34 | Frame Shift Ins (INS) | VAF 109/268 reads (41%) | catalogued as rs751612825; called by mutect2, varscan2
- CCDC181 | c.1258A>T p.K420* (on ENST00000367806 / NM_001300969.1; = p.K419* on NM_021179.2) | Nonsense Mutation (SNP) | VAF 57/156 reads (37%) | catalogued as rs1048688163, COSV61392567, COSV61393785; called by muse, mutect2, varscan2
- CCDC22 | c.1151G>A p.R384H | Missense Mutation (SNP) | VAF 112/287 reads (39%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.947); catalogued as rs782549631; called by muse, mutect2, varscan2
- CCDC61 | c.1319G>A p.R440H | Missense Mutation (SNP) | VAF 50/156 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs1192247060; called by muse, mutect2, varscan2
- CCDC7 | c.3242C>T p.T1081M | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.011); catalogued as rs146947430; called by muse, mutect2, varscan2
- CCDC71 | c.670C>T p.R224W | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs772931427; called by muse, mutect2
- CCN1 | c.1039G>A p.V347I | Missense Mutation (SNP) | VAF 107/270 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.229); catalogued as rs775270401; called by muse, mutect2, varscan2
- CCR9 | c.181G>A p.V61M (on ENST00000357632 / NM_031200.3; = p.V49M on NM_006641.4) | Missense Mutation (SNP) | VAF 96/252 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.514); catalogued as rs56192301; called by muse, mutect2, varscan2
- CCT5 | c.403G>A p.D135N | Missense Mutation (SNP) | VAF 82/205 reads (40%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as rs751401579, COSV54725075; called by muse, mutect2, varscan2
- CDC20 | c.1435C>T p.R479W | Missense Mutation (SNP) | VAF 105/237 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs747796157, COSV100196729; called by muse, varscan2
- CDC42BPG | c.3211G>A p.A1071T | Missense Mutation (SNP) | VAF 54/146 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs760248646; called by muse, mutect2, varscan2
- CDC42EP4 | c.326C>T p.S109L | Missense Mutation (SNP) | VAF 83/203 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs776312011, COSV100231735; called by muse, mutect2, varscan2
- CDCA3 | c.658C>T p.R220W | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as rs148172476; called by muse, mutect2, varscan2
- CDCA7L | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 62/152 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs374550676; called by muse, varscan2
- CDH24 | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs754117962, COSV52977988; called by muse, mutect2, varscan2
- CDH5 | c.1903G>A p.V635M | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.742); catalogued as rs1052074953, COSV58516214; called by muse, mutect2, varscan2
- CDK11A | c.376C>T p.R126* (on ENST00000378633 / NM_001313896.2; = p.R136* on NM_024011.4) | Nonsense Mutation (SNP) | VAF 88/282 reads (31%) | catalogued as rs1240371604; called by muse, mutect2, varscan2
- CDK12 | c.2350C>T p.R784* | Nonsense Mutation (SNP) | VAF 85/228 reads (37%) | catalogued as COSV71002558; called by muse, mutect2, varscan2
- CELSR3 | c.3058C>T p.R1020C | Missense Mutation (SNP) | VAF 144/404 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369332360; called by muse, mutect2, varscan2
- CERS6 | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 72/188 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs755919514, COSV59834601; called by muse, mutect2, varscan2
- CES4A | c.1150C>T p.R384C | Missense Mutation (SNP) | VAF 48/142 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs992066617; called by muse, mutect2, varscan2
- CFAP221 | c.1387C>T p.R463W | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs550330366, COSV99732004; called by muse, mutect2, varscan2
- CFAP299 | c.245C>T p.T82M | Missense Mutation (SNP) | VAF 68/155 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.541); catalogued as rs765782959, COSV63872319; called by muse, mutect2, varscan2
- CFAP47 | c.7601A>G p.N2534S | Missense Mutation (SNP) | VAF 60/171 reads (35%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV66216677; called by muse, mutect2, varscan2
- CFAP69 | c.1872del p.K624Nfs*5 | Frame Shift Del (DEL) | VAF 82/202 reads (41%) | catalogued as rs763364101; called by mutect2, varscan2
- CFAP69 | c.2726C>T p.T909M | Missense Mutation (SNP) | VAF 67/236 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs747560061; called by muse, varscan2
- CFAP74 | c.4261G>A p.V1421M | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs373347486; called by muse, mutect2
- CHAMP1 | c.1418G>A p.R473H | Missense Mutation (SNP) | VAF 83/216 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs548630533; called by muse, mutect2, varscan2
- CHD4 | c.4354C>T p.R1452W (on ENST00000357008 / NM_001363606.2; = p.R1465W on NM_001273.5) | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1321427698, COSV58896314; called by muse, mutect2, varscan2
- CHD4 | c.2335C>T p.R779W (on ENST00000357008 / NM_001363606.2; = p.R792W on NM_001273.5) | Missense Mutation (SNP) | VAF 89/243 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58901404; called by muse, varscan2
- CHD5 | c.5213G>A p.R1738Q | Missense Mutation (SNP) | VAF 42/141 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs1360828017; called by muse, mutect2, varscan2
- CHD6 | c.2683C>T p.R895C | Missense Mutation (SNP) | VAF 7/162 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100498315; called by muse, mutect2
- CHERP | c.1282G>A p.V428M | Missense Mutation (SNP) | VAF 83/215 reads (39%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.037); catalogued as rs773224330; called by muse, mutect2, varscan2
- CHFR | c.38C>A p.P13Q | Missense Mutation (SNP) | VAF 52/129 reads (40%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1407689006, COSV57173272; called by muse, mutect2, varscan2
- CIT | c.1556G>A p.R519Q | Missense Mutation (SNP) | VAF 50/141 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as rs746417068; called by muse, mutect2, varscan2
- CLIP3 | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV62112303; called by muse, mutect2, varscan2
- CLPTM1L | c.476C>T p.P159L | Missense Mutation (SNP) | VAF 55/117 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs376202682; called by muse, mutect2, varscan2
- CNGA1 | c.604G>A p.V202I | Missense Mutation (SNP) | VAF 71/187 reads (38%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as rs764278660; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNNM1 | c.298G>A p.G100S | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as COSV100763811; called by muse, mutect2, varscan2
- CNTNAP5 | c.1834G>A p.G612S | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756000668, COSV70498892; called by muse, mutect2, varscan2
- COL18A1 | c.4487G>A p.R1496Q (on ENST00000359759 / NM_130444.3; = p.R1261Q on NM_030582.4) | Missense Mutation (SNP) | VAF 102/288 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as rs199583095; called by muse, mutect2, varscan2
- COL28A1 | c.380T>C p.I127T | Missense Mutation (SNP) | VAF 74/182 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.133); catalogued as rs748878046; called by muse, mutect2, varscan2
- COL4A1 | c.4882G>A p.A1628T | Missense Mutation (SNP) | VAF 40/456 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.062); catalogued as rs144201848; called by muse, mutect2
- COL4A6 | c.3496G>T p.G1166C | Missense Mutation (SNP) | VAF 35/232 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57883472; called by muse, mutect2, varscan2
- COL7A1 | c.3148C>T p.R1050C | Missense Mutation (SNP) | VAF 119/344 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.232); catalogued as rs2229818, CD023249; called by muse, mutect2, varscan2
- COLGALT1 | c.676C>T p.R226W | Missense Mutation (SNP) | VAF 43/495 reads (9%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.462); catalogued as rs767735851; called by muse, mutect2
- CPAMD8 | c.2593G>A p.G865R (on ENST00000651564; = p.G818R on NM_015692.5) | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs1001388479; called by muse, mutect2, varscan2
- CPEB3 | c.1783C>T p.R595C | Missense Mutation (SNP) | VAF 42/433 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); catalogued as rs1158230101; called by muse, mutect2, varscan2
- CPNE1 | c.1459C>T p.R487C (on ENST00000352393; = p.R492C on NM_003915.5) | Missense Mutation (SNP) | VAF 141/244 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.113); catalogued as rs185008214, COSV100468208; called by muse, mutect2, varscan2
- CPNE7 | c.1724G>A p.R575Q | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs573409569, COSV52014170; called by muse, mutect2, varscan2
- CPSF1 | c.1099G>A p.A367T | Missense Mutation (SNP) | VAF 87/220 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.833); catalogued as rs1564692627; called by muse, mutect2, varscan2
- CRABP2 | c.377C>T p.A126V | Missense Mutation (SNP) | VAF 61/148 reads (41%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.551); catalogued as rs139620782; called by muse, mutect2, varscan2
- CRACD | c.1063G>A p.A355T | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.073); catalogued as rs568276295, COSV51715441; called by muse, mutect2, varscan2
- CRTC2 | c.1136G>A p.R379H | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs143226168; called by muse, mutect2, varscan2
- CRY2 | c.1157G>A p.R386H | Missense Mutation (SNP) | VAF 49/115 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1357448873; called by muse, mutect2, varscan2
- CSMD1 | c.2728G>A p.E910K (on ENST00000520002; = p.E909K on NM_033225.6) | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.22); catalogued as rs191881393; called by muse, mutect2, varscan2
- CSRNP2 | c.1532G>A p.R511H | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs759341085, COSV50398530; called by muse, mutect2, varscan2
- CSRNP3 | c.730G>A p.G244S | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs569988957; called by muse, mutect2, varscan2
- CTBP1 | c.997C>T p.R333W | Missense Mutation (SNP) | VAF 18/286 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs1329666542, COSV52074127; called by muse, mutect2
- CTC1 | c.421G>A p.V141I | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs532695142, COSV59853290; called by muse, mutect2, varscan2
- CTRB1 | c.229G>A p.G77R | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.031); catalogued as rs1395895685; called by mutect2, varscan2
- CTTN | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 62/158 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs377163101; called by muse, mutect2, varscan2
- CUTC | c.505G>A p.V169M | Missense Mutation (SNP) | VAF 94/264 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1373070986, COSV65081654; called by muse, mutect2, varscan2
- CYP19A1 | c.466G>A p.G156S | Missense Mutation (SNP) | VAF 130/325 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.258); catalogued as rs757460733; called by muse, mutect2, varscan2
- CYP1B1 | c.868del p.R290Afs*3 | Frame Shift Del (DEL) | VAF 136/402 reads (34%) | catalogued as COSV99037570; called by mutect2, pindel, varscan2
- CYP20A1 | c.484G>A p.V162M | Missense Mutation (SNP) | VAF 99/233 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.315); catalogued as rs778631685, COSV61909692; called by muse, mutect2, varscan2
- CYP26B1 | c.902C>T p.T301M | Missense Mutation (SNP) | VAF 76/215 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs765773815, COSV50010901; called by muse, mutect2, varscan2
- CYP4A22 | c.511-1G>T p.X171_splice | Splice Site (SNP) | VAF 65/135 reads (48%) | catalogued as rs372302534; called by muse, mutect2, varscan2
- CYP51A1 | c.1421G>A p.R474H | Missense Mutation (SNP) | VAF 19/214 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); catalogued as rs1046740950, COSV50154675; called by muse, mutect2
- CYSLTR1 | c.949G>A p.V317M | Missense Mutation (SNP) | VAF 59/140 reads (42%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs779571076, COSV104428443, COSV99055205; called by muse, mutect2
- DBNDD2 | c.658G>A p.D220N | Missense Mutation (SNP) | VAF 147/588 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs775427994; called by muse, varscan2
- DEAF1 | c.781C>T p.R261* | Nonsense Mutation (SNP) | VAF 140/412 reads (34%) | catalogued as rs778326610; called by muse, mutect2, varscan2
- DENND2B | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs141444386, COSV58204703; called by muse, mutect2, varscan2
- DGKA | c.1606C>T p.R536* | Nonsense Mutation (SNP) | VAF 36/110 reads (33%) | catalogued as rs760208861; called by muse, mutect2, varscan2
- DGKK | c.629C>T p.S210L | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV65706810; called by muse, mutect2, varscan2
- DGKQ | c.1966G>A p.A656T | Missense Mutation (SNP) | VAF 46/156 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.916); catalogued as rs370473571; called by muse, mutect2, varscan2
- DHX9 | c.1366C>T p.R456* | Nonsense Mutation (SNP) | VAF 58/186 reads (31%) | catalogued as rs1429406589; called by muse, mutect2, varscan2
- DLEC1 | c.3493C>A p.L1165M | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.077); catalogued as rs200205214; called by muse, mutect2, varscan2
- DLG1 | c.2627C>T p.T876M (on ENST00000419354 / NM_001290983.1; = p.T898M on NM_004087.2) | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs765371853; called by muse, mutect2, varscan2
- DMGDH | c.1482C>G p.H494Q | Missense Mutation (SNP) | VAF 118/473 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs949520858; called by muse, mutect2, varscan2
- DMTF1 | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as rs559006713, COSV58685724; called by muse, mutect2, varscan2
- DNAH3 | c.10991C>T p.A3664V | Missense Mutation (SNP) | VAF 95/247 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.084); catalogued as rs762473456, COSV54529556; called by muse, mutect2, varscan2
- DNAH5 | c.2825C>T p.T942M | Missense Mutation (SNP) | VAF 22/396 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1332078256, COSV99455366; called by muse, mutect2
- DNAJB6 | c.815C>T p.A272V | Missense Mutation (SNP) | VAF 87/237 reads (37%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs978425267; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- DNASE1 | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 158/446 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs774890803, COSV55913317; called by muse, mutect2, varscan2
- DOCK4 | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as COSV70318651; called by muse, mutect2
- DOCK6 | c.4894G>A p.A1632T | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs778556445; called by muse, mutect2, varscan2
- DOCK7 | c.2998G>A p.V1000I (on ENST00000635253 / NM_001367561.1; = p.V969I on NM_033407.3) | Missense Mutation (SNP) | VAF 32/238 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as rs759268031, COSV52004740, COSV99226751; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DOK3 | c.208C>T p.R70W | Missense Mutation (SNP) | VAF 26/278 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1288621558, COSV100394315; called by muse, mutect2
- DOT1L | c.2566G>A p.G856S | Missense Mutation (SNP) | VAF 88/192 reads (46%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0.005); catalogued as rs760010356, COSV67112508; called by muse, mutect2, varscan2
- DPP9 | c.1918G>A p.V640I (on ENST00000598800; = p.V669I on NM_139159.5) | Missense Mutation (SNP) | VAF 89/201 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as rs772138491; called by muse, mutect2, varscan2
- DRD4 | c.1247G>A p.R416H | Missense Mutation (SNP) | VAF 119/314 reads (38%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs377409215; called by muse, mutect2, varscan2
- DRD5 | c.1145C>T p.T382M | Missense Mutation (SNP) | VAF 79/222 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs775864675, COSV58576954; called by muse, mutect2, varscan2
- DSG3 | c.2135C>T p.A712V | Missense Mutation (SNP) | VAF 59/122 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768429518, COSV57124793; called by muse, mutect2
- DUSP29 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 88/349 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.699); catalogued as COSV100633415; called by muse, mutect2, varscan2
- E2F1 | c.493C>T p.R165W | Missense Mutation (SNP) | VAF 355/704 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58535777; called by muse, mutect2, varscan2
- EBF3 | c.1232C>T p.A411V (on ENST00000355311 / NM_001375392.1; = p.A402V on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.09); catalogued as rs746878929; called by muse, mutect2, varscan2
- ECHDC2 | c.749C>T p.T250M (on ENST00000371522 / NM_001198961.2; = p.T219M on NM_018281.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 106/300 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs755455022; called by muse, mutect2, varscan2
- ECM1 | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as rs769174923; called by muse, mutect2, varscan2
- EDC4 | c.3851C>T p.A1284V | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs367900519; called by muse, mutect2, varscan2
- EDRF1 | c.2858G>A p.R953Q (on ENST00000356792 / NM_001202438.2; = p.R919Q on NM_015608.2) | Missense Mutation (SNP) | VAF 20/362 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs920683189, COSV61764621; called by muse, mutect2
- EFNB2 | c.847G>A p.G283S | Missense Mutation (SNP) | VAF 32/217 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1566453711, COSV55363294; called by muse, mutect2, varscan2
- EFS | c.31C>T p.R11W | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs764268978; called by muse, mutect2
- EIF2A | c.1550G>A p.S517N | Missense Mutation (SNP) | VAF 30/336 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV99855791; called by muse, mutect2
- EIF4G3 | c.4360G>A p.E1454K | Missense Mutation (SNP) | VAF 84/216 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs776441355; called by muse, mutect2, varscan2
- EML2 | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 56/145 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200186061; called by muse, mutect2, varscan2
- ENTPD2 | c.571C>T p.R191W | Missense Mutation (SNP) | VAF 97/262 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs371276900; called by muse, mutect2, varscan2
- EPHA6 | c.1945G>A p.A649T (on ENST00000389672 / NM_001080448.3; = p.A41T on NM_173655.4) | Missense Mutation (SNP) | VAF 59/165 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs1323884785, COSV67575443; called by muse, mutect2, varscan2
- EPHB6 | c.958C>T p.R320W | Missense Mutation (SNP) | VAF 107/282 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as rs745425973, COSV67418697; called by muse, mutect2, varscan2
- EPPK1 | c.4166C>T p.T1389M | Missense Mutation (SNP) | VAF 87/239 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs1361492526; called by muse, mutect2, varscan2
- EPPK1 | c.2555G>A p.R852H | Missense Mutation (SNP) | VAF 12/163 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs781877845, COSV73261509; called by muse, mutect2
- ESPL1 | c.5092C>T p.R1698C | Missense Mutation (SNP) | VAF 53/118 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1473544704, COSV57759574; called by muse, mutect2, varscan2
- EVPL | c.2083G>A p.A695T | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as rs1347136164, COSV56915339; called by muse, mutect2, varscan2
- EXOC1 | c.56G>A p.R19H | Missense Mutation (SNP) | VAF 61/157 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs192310507; called by muse, mutect2, varscan2
- EXOSC9 | c.685C>T p.R229* | Nonsense Mutation (SNP) | VAF 91/232 reads (39%) | catalogued as rs935979786; called by muse, mutect2, varscan2
- F7 | c.452G>A p.C151Y | Missense Mutation (SNP) | VAF 134/332 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM002762; called by muse, mutect2, varscan2
- FAM102A | c.682C>T p.R228C (on ENST00000373095 / NM_001035254.3; = p.R86C on NM_203305.2) | Missense Mutation (SNP) | VAF 73/248 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs751138011; called by muse, mutect2, varscan2
- FAM118B | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 62/155 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as rs753783931, COSV64157556; called by muse, varscan2
- FAM160A1 | c.190G>A p.V64M | Missense Mutation (SNP) | VAF 78/198 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs746592641; called by muse, mutect2, varscan2
- FAM166C | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 35/177 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as rs1336036395, COSV61593051, COSV61593272; called by muse, mutect2, varscan2
- FAM205A | c.3947G>A p.R1316H | Missense Mutation (SNP) | VAF 68/184 reads (37%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs1411390215; called by muse, mutect2, varscan2
- FAM47A | c.1235G>A p.R412H | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.735); catalogued as rs371474916, COSV60496032; called by muse, mutect2, varscan2
- FAM71E2 | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as rs1346347734; called by muse, mutect2, varscan2
- FAM83C | c.64C>T p.R22W | Missense Mutation (SNP) | VAF 86/295 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377344891; called by muse, mutect2, varscan2
- FAM83G | c.1804C>T p.R602C | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1197063594, COSV100524689; called by muse, mutect2, varscan2
- FAM98B | c.612G>A p.A204= | Splice Region (SNP) | VAF 10/95 reads (11%) | catalogued as rs766223410, COSV99989055; called by muse, mutect2, varscan2
- FAM9B | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.948); catalogued as rs200690989; called by muse, mutect2, varscan2
- FAS | c.403del p.C135Vfs*52 | Frame Shift Del (DEL) | VAF 150/372 reads (40%) | catalogued as rs1564692984, CX113055, COSV58238368; called by mutect2, varscan2
- FAT2 | c.2567G>A p.R856H | Missense Mutation (SNP) | VAF 77/208 reads (37%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.938); catalogued as rs747640599; called by muse, mutect2, varscan2
- FAT4 | c.12100G>A p.E4034K | Missense Mutation (SNP) | VAF 91/274 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as rs1277850395, COSV58671125; called by muse, mutect2, varscan2
- FBXO46 | c.1636C>T p.R546C | Missense Mutation (SNP) | VAF 70/181 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs745615697; called by muse, mutect2, varscan2
- FBXO7 | c.1141C>T p.R381* | Nonsense Mutation (SNP) | VAF 161/450 reads (36%) | catalogued as rs78099169, COSV56676287; called by muse, mutect2, varscan2
- FBXO9 | c.805G>A p.V269M | Missense Mutation (SNP) | VAF 52/131 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs758378594, COSV55057826; called by muse, mutect2, varscan2
- FCGR2A | c.461T>C p.V154A (on ENST00000271450 / NM_001136219.3; = p.V153A on NM_021642.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/513 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1224632935; called by muse, mutect2
- FGFRL1 | c.1046G>A p.R349H | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1009734189, COSV53256446; called by muse, mutect2
- FHOD1 | c.1048C>T p.R350W | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99264260; called by muse, mutect2, varscan2
- FKBP10 | c.1130C>T p.A377V | Missense Mutation (SNP) | VAF 90/210 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.018); catalogued as rs782640718; called by muse, mutect2, varscan2
- FLG | c.2338C>T p.R780C | Missense Mutation (SNP) | VAF 185/544 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.042); catalogued as rs753102917, COSV64242581; called by muse, mutect2, varscan2
- FLII | c.2389C>T p.R797C | Missense Mutation (SNP) | VAF 44/147 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368913764; called by muse, mutect2, varscan2
- FLII | c.832C>T p.R278* | Nonsense Mutation (SNP) | VAF 40/108 reads (37%) | catalogued as rs1259907837; called by muse, mutect2, varscan2
- FLT1 | c.406G>A p.V136I | Missense Mutation (SNP) | VAF 93/272 reads (34%) | SIFT tolerated (0.91); PolyPhen benign (0.006); catalogued as rs373801409; called by muse, mutect2, varscan2
- FLT3LG | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs375362082; called by muse, mutect2, varscan2
- FLYWCH1 | c.1248G>A p.P416= (on ENST00000253928 / NM_001308068.2; = p.P415= on NM_020912.1 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 21/56 reads (38%) | catalogued as rs200725863; called by muse, mutect2, varscan2
- FNDC4 | c.629C>T p.P210L | Missense Mutation (SNP) | VAF 37/283 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as rs1356804969; called by muse, mutect2, varscan2
- FOXA2 | c.748C>T p.R250C (on ENST00000377115 / NM_153675.3; = p.R256C on NM_021784.5) | Missense Mutation (SNP) | VAF 11/231 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65795953; called by muse, mutect2
- FOXD4L4 | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 258/924 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as rs1167367534; called by muse, mutect2, varscan2
- FREM2 | c.8533C>T p.R2845* | Nonsense Mutation (SNP) | VAF 24/404 reads (6%) | catalogued as rs371448296, COSV99748987; called by muse, mutect2
- FURIN | c.1720G>A p.A574T | Missense Mutation (SNP) | VAF 73/223 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.029); catalogued as rs1274395518, COSV99184749; called by muse, mutect2, varscan2
- FYN | c.44C>T p.T15M | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.097); catalogued as rs140762956, COSV57614854; called by muse, mutect2
- FZD6 | c.1103G>A p.R368H | Missense Mutation (SNP) | VAF 23/216 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs375068426; called by muse, mutect2, varscan2
- G6PD | c.829G>A p.A277T | Missense Mutation (SNP) | VAF 47/152 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as rs1557230050, COSV63702853; called by muse, mutect2, varscan2
- GAB2 | c.1240C>T p.R414C (on ENST00000361507 / NM_080491.3; = p.R376C on NM_012296.3) | Missense Mutation (SNP) | VAF 85/229 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.232); catalogued as rs373502813, COSV60866900; called by muse, mutect2, varscan2
- GABRA1 | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 120/323 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.713); catalogued as COSV50100480; called by muse, mutect2, varscan2
- GALNT12 | c.1706C>T p.S569L | Missense Mutation (SNP) | VAF 40/485 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as rs199958039; ClinVar: uncertain significance; called by muse, mutect2
- GALR2 | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 130/368 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778084055, COSV57161567; called by muse, mutect2, varscan2
- GBP5 | c.731dup p.L245Afs*5 | Frame Shift Ins (INS) | VAF 112/286 reads (39%) | catalogued as rs34148688; called by mutect2, varscan2
- GCKR | c.1606G>A p.E536K | Missense Mutation (SNP) | VAF 31/476 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.03); catalogued as rs772997882, COSV53107101; called by muse, mutect2
- GDI2 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 78/186 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.284); catalogued as rs1271271901; called by muse, varscan2
- GFOD1 | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 58/149 reads (39%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.899); catalogued as rs1188656051, COSV64955027; called by muse, mutect2, varscan2
- GGT7 | c.323C>T p.T108M | Missense Mutation (SNP) | VAF 80/403 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.753); catalogued as rs1568941335, COSV60542474; called by muse, mutect2, varscan2
- GIGYF1 | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 68/188 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.041); catalogued as rs753444113; called by muse, mutect2, varscan2
- GIPR | c.91A>G p.T31A | Missense Mutation (SNP) | VAF 67/177 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs1238439945; called by muse, mutect2, varscan2
- GK3P | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 182/514 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.176); catalogued as rs749512650; called by muse, mutect2, varscan2
- GLCCI1 | c.880C>T p.R294C | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as rs912783546, COSV99780339; called by muse, mutect2, varscan2
- GLYR1 | c.1017+1G>A p.X339_splice | Splice Site (SNP) | VAF 66/184 reads (36%) | catalogued as rs1401515942, COSV58927282; called by muse, mutect2, varscan2
- GLYR1 | c.232C>T p.R78* | Nonsense Mutation (SNP) | VAF 65/147 reads (44%) | catalogued as COSV58925540; called by muse, mutect2, varscan2
- GNPTAB | c.2482G>A p.G828R | Missense Mutation (SNP) | VAF 53/145 reads (37%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs772859541; called by muse, mutect2, varscan2
- GNPTAB | c.571+5G>T | Splice Region (SNP) | VAF 60/179 reads (34%) | catalogued as rs1350920642; called by muse, mutect2, varscan2
- GNPTG | c.916T>C p.*306Rext*45 | Nonstop Mutation (SNP) | VAF 163/470 reads (35%) | catalogued as rs1180995978; called by muse, mutect2, varscan2
- GPR37 | c.1444C>T p.R482W | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs767810765, COSV58259947; called by muse, mutect2, varscan2
- GPSM1 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 28/262 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs558413197; called by muse, mutect2, varscan2
- GRIK2 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0.026); catalogued as COSV100024396, COSV59710691; called by muse, varscan2
- GRIN2C | c.2702G>A p.R901H | Missense Mutation (SNP) | VAF 139/387 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs1270170226; called by muse, mutect2, varscan2
- GRM2 | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 152/340 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs770473805; called by muse, mutect2, varscan2
- GTF3C1 | c.4058G>A p.R1353Q | Missense Mutation (SNP) | VAF 59/164 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV62238936; called by muse, mutect2, varscan2
- GXYLT1 | c.26T>C p.V9A | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.007); catalogued as rs1309618680; called by muse, mutect2, varscan2
- HCN1 | c.2201C>T p.P734L | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs772962018, COSV57526034; called by muse, mutect2, varscan2
- HERC2 | c.2665G>A p.V889M | Missense Mutation (SNP) | VAF 32/284 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs1489133767; called by muse, mutect2, varscan2
- HK3 | c.2625G>A p.P875= | Splice Region (SNP) | VAF 62/155 reads (40%) | catalogued as rs755376392, COSV52838173, COSV52843867; called by muse, mutect2, varscan2
- HPS6 | c.2077C>T p.R693C | Missense Mutation (SNP) | VAF 187/483 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs759990152; called by muse, mutect2, varscan2
- HTT | c.9187G>A p.A3063T | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as rs1316267315, COSV61864521; called by muse, mutect2, varscan2
- HYOU1 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 59/132 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101345545, COSV101345709; called by muse, mutect2
- IDUA | c.382C>T p.P128S | Missense Mutation (SNP) | VAF 45/368 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs754674352; called by muse, mutect2, varscan2
- IFRD2 | c.769G>A p.V257M | Missense Mutation (SNP) | VAF 129/336 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs371590180, COSV57115417; called by muse, mutect2, varscan2
- IFT122 | c.2332G>A p.V778I (on ENST00000348417 / NM_052989.3; = p.V719I on NM_018262.4) | Missense Mutation (SNP) | VAF 50/391 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs139943115; called by muse, mutect2, varscan2
- IGHG1 | c.148G>A p.V50M | Missense Mutation (SNP) | VAF 218/706 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs757428575; called by mutect2, varscan2
- IGHV3-74 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 12/388 reads (3%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.009); catalogued as rs754371505; called by muse, mutect2
- IGSF3 | c.1261G>A p.V421I (on ENST00000369486 / NM_001007237.3; = p.V441I on NM_001542.4) | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs561682711, COSV59590696; called by muse, mutect2
- IK | c.1115G>A p.R372Q | Missense Mutation (SNP) | VAF 30/376 reads (8%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.885); catalogued as rs746748598, COSV70258310; called by muse, mutect2
- IKZF1 | c.982C>T p.R328C | Missense Mutation (SNP) | VAF 18/260 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58792054; called by muse, mutect2
- IL22 | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV60160816; called by muse, mutect2, varscan2
- ILF3 | c.1666G>A p.V556I | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.2); catalogued as rs914167445, COSV51556389; called by muse, mutect2, varscan2
- ILF3 | c.2174C>T p.P725L | Missense Mutation (SNP) | VAF 100/327 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as rs776639977; called by muse, mutect2, varscan2
- IMPA2 | c.850C>T p.R284W | Missense Mutation (SNP) | VAF 80/185 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747599022, COSV52318714; called by muse, mutect2, varscan2
- INPP5J | c.2866C>T p.R956* (on ENST00000331075 / NM_001284285.2; = p.R588* on NM_001002837.2) | Nonsense Mutation (SNP) | VAF 31/75 reads (41%) | catalogued as rs755873211; called by muse, mutect2, varscan2
- INTS1 | c.2938G>A p.G980S | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200366736, COSV101248261; called by muse, mutect2, varscan2
- IQSEC3 | c.1643C>T p.A548V (on ENST00000538872 / NM_001170738.2; = p.A245V on NM_015232.1) | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1555087977; called by muse, mutect2, varscan2
- IRF2 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 43/147 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0.006); catalogued as COSV66928628; called by muse, mutect2, varscan2
- IRS1 | c.1791del p.H598Tfs*38 | Frame Shift Del (DEL) | VAF 4/16 reads (25%) | catalogued as rs761880048; called by mutect2, varscan2
- IRS4 | c.3191G>A p.R1064Q | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); catalogued as COSV100929784; called by muse, mutect2, varscan2
- IRX4 | c.590G>A p.R197H | Missense Mutation (SNP) | VAF 88/290 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs373640113, COSV51474859; called by muse, varscan2
- ITGA7 | c.2312G>A p.R771Q (on ENST00000555728; = p.R727Q on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 148/469 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.327); catalogued as rs371276793; called by muse, mutect2, varscan2
- ITGAL | c.3247G>A p.V1083M | Missense Mutation (SNP) | VAF 61/184 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.049); catalogued as rs762893364, COSV63322176; called by muse, mutect2, varscan2
- ITIH4 | c.2432C>T p.A811V | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.282); catalogued as rs535415256, COSV56574465; called by muse, mutect2, varscan2
- ITPKB | c.2564G>A p.R855Q | Missense Mutation (SNP) | VAF 60/184 reads (33%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.845); catalogued as rs1174457089, COSV99684823; called by muse, mutect2, varscan2
- ITPRID1 | c.3106del p.S1036Lfs*13 | Frame Shift Del (DEL) | VAF 39/80 reads (49%) | catalogued as rs35589779; called by mutect2, varscan2
- ITSN2 | c.1366C>T p.R456* | Nonsense Mutation (SNP) | VAF 56/141 reads (40%) | catalogued as rs764665587, COSV61943876; called by muse, varscan2
- IVD | c.1004G>A p.R335H (on ENST00000651168; = p.R332H on NM_002225.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 92/267 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.069); catalogued as rs745464766; called by muse, mutect2, varscan2
- JAG1 | c.3286C>T p.R1096W | Missense Mutation (SNP) | VAF 68/247 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs537986153, COSV54756564; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- JAG2 | c.3619C>T p.R1207C | Missense Mutation (SNP) | VAF 143/362 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs150102743; called by muse, mutect2, varscan2
- JAKMIP3 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 186/507 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.749); catalogued as rs778567934, COSV53827124; called by muse, mutect2, varscan2
- JARID2 | c.1858C>T p.R620C | Missense Mutation (SNP) | VAF 58/172 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.093); catalogued as COSV59188588; called by muse, mutect2, varscan2
- KAT6A | c.4189G>A p.E1397K | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.196); catalogued as rs796200647, COSV55905718; called by muse, mutect2
- KCNJ14 | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1316728420; called by muse, mutect2, varscan2
- KCNJ3 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 14/244 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54534252; called by muse, mutect2
- KCNK4 | c.314-6G>A | Splice Region (SNP) | VAF 78/177 reads (44%) | catalogued as COSV60455021; called by muse, mutect2, varscan2
- KCNS1 | c.1081G>A p.G361R | Missense Mutation (SNP) | VAF 12/151 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148084401; called by muse, mutect2
- KCNV2 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761130319, COSV66056684; called by muse, mutect2, varscan2
- KCNV2 | c.1192C>T p.R398C | Missense Mutation (SNP) | VAF 48/408 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779297718; called by muse, mutect2, varscan2
- KDM4C | c.202C>T p.L68F | Missense Mutation (SNP) | VAF 62/164 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs145963260; called by muse, mutect2, varscan2
- KDM4C | c.1921A>G p.M641V | Missense Mutation (SNP) | VAF 70/167 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs1311577015; called by muse, mutect2, varscan2
- KEL | c.256C>T p.R86W | Missense Mutation (SNP) | VAF 108/273 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.27); catalogued as rs1009140606, COSV100786888; called by muse, mutect2, varscan2
- KIAA0100 | c.1787G>A p.R596Q | Missense Mutation (SNP) | VAF 115/269 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs909150372, COSV66496200; called by muse, mutect2, varscan2
- KIAA1522 | c.554C>T p.T185M (on ENST00000373480 / NM_001198972.2; = p.T244M on NM_020888.3) | Missense Mutation (SNP) | VAF 57/186 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.188); catalogued as rs759539643; called by muse, mutect2, varscan2
- KIAA2013 | c.1765G>A p.G589R | Missense Mutation (SNP) | VAF 57/151 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs781323139; called by muse, mutect2, varscan2
- KIF13B | c.5392G>A p.A1798T | Missense Mutation (SNP) | VAF 113/279 reads (41%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.024); catalogued as rs370028815; called by muse, mutect2, varscan2
- KIF23 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372849416; called by muse, mutect2, varscan2
- KIF26B | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 89/218 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs779913549; called by muse, mutect2, varscan2
- KIF26B | c.4234G>A p.A1412T | Missense Mutation (SNP) | VAF 50/136 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs374646652; called by muse, mutect2, varscan2
- KIF5C | c.839G>A p.R280Q | Missense Mutation (SNP) | VAF 59/125 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV68479751; called by muse, mutect2, varscan2
- KIF7 | c.2783C>T p.A928V | Missense Mutation (SNP) | VAF 110/264 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.493); catalogued as rs764218371; called by muse, varscan2
- KIT | c.1615A>G p.I539V | Missense Mutation (SNP) | VAF 133/377 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs1476093811, COSV55429876; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KLHL13 | c.1888C>T p.R630C | Missense Mutation (SNP) | VAF 88/212 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV53245841; called by muse, mutect2, varscan2
- KLHL17 | c.1706C>T p.T569M | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs370976650; called by muse, mutect2
- KLRC3 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 19/172 reads (11%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs370768044; called by muse, varscan2
- KMT2B | c.1753C>T p.R585C | Missense Mutation (SNP) | VAF 54/121 reads (45%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs760508345; called by muse, mutect2, varscan2
- KMT5C | c.897C>T p.A299= | Splice Region (SNP) | VAF 12/118 reads (10%) | catalogued as rs200304797; called by muse, mutect2, varscan2
- KMT5C | c.1295C>T p.A432V | Missense Mutation (SNP) | VAF 58/159 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.027); catalogued as rs754747560; called by muse, mutect2, varscan2
- KRT20 | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 122/256 reads (48%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV51424591; called by muse, mutect2, varscan2
- KRT31 | c.125G>A p.S42N | Missense Mutation (SNP) | VAF 193/569 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as rs780413177, COSV52437611; called by muse, mutect2, varscan2
- KRTAP19-5 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 38/321 reads (12%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.013); catalogued as rs746949932, COSV61859197, COSV61859917; called by muse, mutect2, varscan2
- LAMA1 | c.4181G>A p.R1394H | Missense Mutation (SNP) | VAF 108/266 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.025); catalogued as rs373119671; called by muse, mutect2, varscan2
- LCE1B | c.73C>A p.L25I | Missense Mutation (SNP) | VAF 105/302 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV63980454, COSV63980713; called by muse, mutect2, varscan2
- LCTL | c.1354T>C p.Y452H | Missense Mutation (SNP) | VAF 19/260 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767986914; called by muse, mutect2
- LHX4 | c.880G>A p.G294R | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.69); PolyPhen benign (0.006); catalogued as rs1274360714, COSV55373050; called by muse, mutect2
- LHX8 | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 52/131 reads (40%) | SIFT tolerated (0.69); PolyPhen benign (0.245); catalogued as rs755492871; called by muse, mutect2, varscan2
- LIPJ | c.676A>G p.N226D | Missense Mutation (SNP) | VAF 66/189 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.047); catalogued as rs887908156; called by muse, mutect2, varscan2
- LRIG1 | c.66G>A p.W22* | Nonsense Mutation (SNP) | VAF 36/95 reads (38%) | catalogued as rs1471562879; called by muse, mutect2, varscan2
- LRP1 | c.11096G>A p.R3699Q | Missense Mutation (SNP) | VAF 85/196 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); catalogued as rs755480423, COSV54514782; called by muse, mutect2, varscan2
- LRRK1 | c.2221C>T p.L741F | Missense Mutation (SNP) | VAF 49/98 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs746593625; called by muse, mutect2, varscan2
- LRRK2 | c.2129del p.N710Mfs*2 | Frame Shift Del (DEL) | VAF 152/408 reads (37%) | catalogued as COSV54153441; called by mutect2, pindel, varscan2
- LYG2 | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 82/251 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs781622268, COSV100283487; called by muse, mutect2, varscan2
- MACROD2 | c.1049G>A p.R350H (on ENST00000642719; = p.R322H on NM_080676.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 85/165 reads (52%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.005); catalogued as rs763015539, COSV53948315; called by muse, mutect2, varscan2
- MAGIX | c.842C>T p.T281M | Missense Mutation (SNP) | VAF 122/325 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.695); catalogued as COSV66256348; called by muse, mutect2, varscan2
- MANBA | c.1558C>T p.R520W (on ENST00000642252; = p.R474W on NM_005908.4) | Missense Mutation (SNP) | VAF 44/385 reads (11%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.498); catalogued as rs141230920; called by muse, mutect2, varscan2
- MAP2K7 | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs942074295, COSV67607842; called by muse, mutect2, varscan2
- MAP3K15 | c.3745C>T p.R1249W | Missense Mutation (SNP) | VAF 77/178 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs763826263; called by muse, mutect2, varscan2
- MAP3K6 | c.3554G>A p.R1185Q | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs766699594; called by muse, mutect2, varscan2
- MAP3K9 | c.2981G>A p.R994Q (on ENST00000554752 / NM_001284230.1; = p.R1008Q on NM_033141.4) | Missense Mutation (SNP) | VAF 155/364 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.212); catalogued as rs774902596, COSV67122426; called by muse, mutect2, varscan2
- MARK3 | c.1975C>T p.R659C (on ENST00000429436 / NM_001128918.3; = p.R635C on NM_002376.6) | Missense Mutation (SNP) | VAF 82/211 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53514431; called by muse, mutect2, varscan2
- MAST2 | c.3367G>A p.V1123I | Missense Mutation (SNP) | VAF 30/279 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.654); catalogued as rs767981878; called by muse, mutect2, varscan2
- MAST2 | c.3697C>T p.R1233C | Missense Mutation (SNP) | VAF 47/97 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs200023429; called by muse, mutect2, varscan2
- MATN4 | c.1408C>T p.R470W (on ENST00000372754; = p.R429W on NM_003833.4) | Missense Mutation (SNP) | VAF 123/211 reads (58%) | PolyPhen probably damaging (0.985); catalogued as rs372468063; called by muse, mutect2, varscan2
- MCAT | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 11/243 reads (5%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV51792025; called by muse, mutect2
- MCF2L | c.1868A>G p.E623G (on ENST00000375608; = p.E591G on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/300 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV65049937; called by muse, mutect2
- MCM3 | c.2029C>T p.R677* (on ENST00000229854 / NM_001366374.2; = p.R667* on NM_002388.6 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 116/314 reads (37%) | catalogued as rs752211824; called by muse, mutect2, varscan2
- MCOLN2 | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1337762397; called by muse, mutect2, varscan2
- MED12 | c.5966G>A p.R1989H | Missense Mutation (SNP) | VAF 109/335 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs1569482448, COSV61360023; called by muse, mutect2, varscan2
- MED13 | c.4529C>T p.A1510V | Missense Mutation (SNP) | VAF 36/284 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs377624680, COSV67263826; called by muse, mutect2, varscan2
- MEGF8 | c.6313G>A p.G2105R (on ENST00000251268 / NM_001271938.2; = p.G2038R on NM_001410.3) | Missense Mutation (SNP) | VAF 62/155 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1438305896, COSV52077971; called by muse, mutect2, varscan2
- METTL15 | c.808C>T p.R270W | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs369114838, COSV100328774; called by muse, mutect2, varscan2
- MEX3B | c.461C>T p.P154L | Missense Mutation (SNP) | VAF 56/121 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.195); catalogued as COSV61662898; called by muse, mutect2, varscan2
- MGA | c.7304G>A p.R2435Q (on ENST00000219905 / NM_001164273.1; = p.R2226Q on NM_001080541.2) | Missense Mutation (SNP) | VAF 133/418 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV54951059, COSV54964414; called by muse, mutect2, varscan2
- MICAL1 | c.2303C>T p.P768L | Missense Mutation (SNP) | VAF 101/233 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs770312041; called by muse, mutect2, varscan2
- MIEF1 | c.128C>T p.T43M | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1368577524, COSV100307563; called by muse, mutect2, varscan2
- MINAR1 | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 96/240 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs779048416, COSV59583026; called by muse, mutect2, varscan2
- MKI67 | c.3140C>T p.T1047M | Missense Mutation (SNP) | VAF 104/296 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs767024436, COSV64076587; called by muse, mutect2, varscan2
- MLX | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 82/241 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs759146238, COSV53816087; called by muse, mutect2, varscan2
- MORC2 | c.2915G>A p.R972Q (on ENST00000397641 / NM_001303256.3; = p.R910Q on NM_014941.3) | Missense Mutation (SNP) | VAF 132/338 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as rs1278082078, COSV53197063; called by muse, mutect2, varscan2
- MPP4 | c.1141C>T p.R381C | Missense Mutation (SNP) | VAF 41/78 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs375529816; called by muse, mutect2, varscan2
- MROH2A | c.1973G>A p.R658Q | Missense Mutation (SNP) | VAF 61/184 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.021); catalogued as rs1201608726; called by muse, mutect2, varscan2
- MSLNL | c.1940C>T p.A647V | Missense Mutation (SNP) | VAF 119/316 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.371); catalogued as rs751684300, COSV53502715; called by muse, mutect2, varscan2
- MUC5B | c.949C>T p.R317W | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as rs565861163; called by muse, mutect2, varscan2
- MUS81 | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 28/194 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1416645763, COSV57260331; called by muse, mutect2, varscan2
- MXRA8 | c.901del p.R301Gfs*107 | Frame Shift Del (DEL) | VAF 88/208 reads (42%) | catalogued as rs764857791; called by mutect2, varscan2
- MYCBPAP | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs375852549; called by muse, mutect2, varscan2
- MYH7B | c.5389C>T p.R1797W | Missense Mutation (SNP) | VAF 67/277 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1216216330, COSV52684344; called by muse, mutect2, varscan2
- MYO10 | c.3667G>A p.G1223R | Missense Mutation (SNP) | VAF 189/484 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1434873123, COSV57016082, COSV57017061; called by muse, mutect2, varscan2
- MYO15A | c.1631G>A p.R544H | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.95); catalogued as rs780547562; called by muse, mutect2, varscan2
- MYO15A | c.2740G>A p.E914K | Missense Mutation (SNP) | VAF 12/216 reads (6%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.29); catalogued as rs1381092097; called by muse, mutect2
- MYO18B | c.6245C>T p.A2082V | Missense Mutation (SNP) | VAF 73/229 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.356); catalogued as rs1166253258; called by muse, mutect2, varscan2
- MYO3A | c.1403A>T p.N468I | Missense Mutation (SNP) | VAF 85/221 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.74); catalogued as COSV56334707; called by muse, mutect2, varscan2
- MYO5B | c.1894G>A p.V632I | Missense Mutation (SNP) | VAF 102/292 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.544); catalogued as rs374640744; called by muse, mutect2, varscan2
- MYO9B | c.5720G>A p.R1907H | Missense Mutation (SNP) | VAF 45/129 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.045); catalogued as rs770678301; called by muse, mutect2, varscan2
- MYORG | c.1270C>T p.R424C | Missense Mutation (SNP) | VAF 63/183 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1399976075, COSV52626732; called by muse, mutect2, varscan2
- MYRF | c.407C>T p.P136L (on ENST00000278836 / NM_001127392.3; = p.P127L on NM_013279.4) | Missense Mutation (SNP) | VAF 6/97 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53887242; called by muse, mutect2
- N4BP2 | c.5158G>A p.G1720S | Missense Mutation (SNP) | VAF 50/157 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.43); catalogued as rs765591027; called by muse, mutect2, varscan2
- NBEA | c.4404G>A p.M1468I | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as COSV59757208; called by muse, mutect2, varscan2
- NCOR1 | c.2446G>A p.A816T | Missense Mutation (SNP) | VAF 64/170 reads (38%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs76080188, COSV51963410, COSV99246114; called by muse, mutect2, varscan2
- NCOR2 | c.2501C>T p.A834V | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs763483936; called by muse, varscan2
- NCR3 | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 96/294 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.988); catalogued as rs1335156338; called by muse, mutect2, varscan2
- NDC80 | c.1726C>T p.R576* | Nonsense Mutation (SNP) | VAF 33/79 reads (42%) | catalogued as rs142173030, COSV99859564; called by muse, mutect2, varscan2
- NDST4 | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs760989212, COSV52127725; called by muse, mutect2, varscan2
- NDUFA12 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 112/318 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs772303498, COSV59845863; called by muse, mutect2, varscan2
- NEFM | c.79G>A p.V27I | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs1284300446, COSV55333281; called by muse, mutect2, varscan2
- NEURL4 | c.3590C>T p.A1197V | Missense Mutation (SNP) | VAF 50/119 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.034); catalogued as rs757576657; called by muse, mutect2, varscan2
- NFATC2 | c.1396C>T p.R466W | Missense Mutation (SNP) | VAF 253/488 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756698530, COSV65357603; called by muse, mutect2, varscan2
- NFATC2 | c.1027C>T p.R343C | Missense Mutation (SNP) | VAF 61/227 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV65355953; called by muse, mutect2, varscan2
- NFXL1 | c.380C>T p.T127M | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as rs1451919026, COSV100216769; called by muse, mutect2, varscan2
- NIBAN1 | c.1538C>T p.A513V | Missense Mutation (SNP) | VAF 88/194 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.602); catalogued as rs750889582, COSV100836667; called by muse, mutect2, varscan2
- NIBAN2 | c.1477C>T p.R493W | Missense Mutation (SNP) | VAF 56/156 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV55940876; called by muse, mutect2, varscan2
- NID2 | c.1624G>A p.V542M | Missense Mutation (SNP) | VAF 19/172 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750209996, COSV99357289; called by muse, mutect2, varscan2
- NKD2 | c.1181C>T p.S394L | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as rs572457358; called by muse, mutect2, varscan2
- NKX1-1 | c.856C>T p.R286C | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as rs1280958300; called by muse, varscan2
- NOL6 | c.3008C>T p.P1003L | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1363612849; called by muse, mutect2, varscan2
- NOSTRIN | c.732C>T p.C244= (on ENST00000317647 / NM_001039724.4; = p.C166= on NM_052946.3) | Splice Region (SNP) | VAF 35/87 reads (40%) | catalogued as rs375159218; called by muse, mutect2, varscan2
- NOTCH2 | c.5176C>T p.R1726C | Missense Mutation (SNP) | VAF 163/419 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV56698087; called by muse, mutect2, varscan2
- NPC1 | c.3754+7G>A | Splice Region (SNP) | VAF 76/233 reads (33%) | catalogued as rs778389667; called by muse, mutect2, varscan2
- NRG3 | c.571G>A p.A191T | Missense Mutation (SNP) | VAF 76/197 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs780092587, COSV100931452; called by muse, mutect2, varscan2
- NRP2 | c.2101C>T p.R701W | Missense Mutation (SNP) | VAF 83/238 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760747816; called by muse, mutect2, varscan2
- NRXN1 | c.3871G>A p.V1291M | Missense Mutation (SNP) | VAF 20/306 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.561); catalogued as rs1183751437; called by muse, mutect2
- NSD1 | c.1492C>T p.R498* | Nonsense Mutation (SNP) | VAF 39/390 reads (10%) | catalogued as CM030068, COSV61770550; called by muse, mutect2, varscan2
- NSD1 | c.3802C>T p.R1268W | Missense Mutation (SNP) | VAF 22/284 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.723); catalogued as rs558018694; called by muse, mutect2
- NWD2 | c.2690G>A p.R897H | Missense Mutation (SNP) | VAF 100/241 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.682); catalogued as rs760833228, COSV100520432; called by muse, mutect2, varscan2
- NXPH3 | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs781447574, COSV60872147; called by muse, mutect2, varscan2
- NYAP1 | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.011); catalogued as rs758533199; called by muse, mutect2
- NYNRIN | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.548); catalogued as rs376552671, COSV101230612; called by muse, mutect2, varscan2
- OBSCN | c.17386G>A p.V5796I | Missense Mutation (SNP) | VAF 135/331 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.557); catalogued as rs761881774; called by muse, mutect2, varscan2
- OGFOD2 | c.550G>A p.G184R (on ENST00000228922 / NM_001304833.1; = p.G124R on NM_024623.3) | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766034439; called by muse, mutect2, varscan2
- OGFR | c.1409C>T p.A470V | Missense Mutation (SNP) | VAF 101/385 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs749941602, COSV51696713; called by muse, mutect2, varscan2
- ONECUT2 | c.1289G>A p.R430H | Missense Mutation (SNP) | VAF 117/310 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1349085016, COSV72153056; called by muse, mutect2, varscan2
- OR13J1 | c.221C>T p.T74M | Missense Mutation (SNP) | VAF 50/127 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs569130181, COSV65069499; called by muse, mutect2, varscan2
- OR2C3 | c.207C>A p.F69L | Missense Mutation (SNP) | VAF 99/247 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as COSV63575231; called by muse, mutect2, varscan2
- OSBPL7 | c.2053G>A p.E685K | Missense Mutation (SNP) | VAF 72/236 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as rs536701820, COSV50109850; called by muse, mutect2, varscan2
- OTOA | c.917A>G p.Q306R | Missense Mutation (SNP) | VAF 162/386 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs769534810; called by muse, mutect2, varscan2
- PABPN1 | c.534+6T>C | Splice Region (SNP) | VAF 23/178 reads (13%) | catalogued as rs1440583945; called by muse, mutect2, varscan2
- PAPLN | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 55/115 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752142488, COSV53715726; called by muse, mutect2, varscan2
- PARP1 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 182/497 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs193238922; called by muse, mutect2, varscan2
- PARP4 | c.3994C>T p.R1332C | Missense Mutation (SNP) | VAF 91/234 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.019); catalogued as rs200648886; called by muse, mutect2, varscan2
- PCDHA2 | c.1451C>T p.A484V | Missense Mutation (SNP) | VAF 62/670 reads (9%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.23); catalogued as rs782310227, COSV65367654, COSV65370923; called by muse, mutect2
- PCDHB15 | c.941C>T p.S314L | Missense Mutation (SNP) | VAF 77/196 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.086); catalogued as COSV50858314; called by muse, mutect2, varscan2
- PCDHB6 | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 72/221 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.999); catalogued as rs879963699, COSV99169881; called by muse, mutect2, varscan2
- PCDHGA12 | c.1603C>T p.R535W | Missense Mutation (SNP) | VAF 75/213 reads (35%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.081); catalogued as COSV52754069; called by muse, mutect2, varscan2
- PCID2 | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 61/156 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as rs200060522; called by muse, mutect2, varscan2
- PCNT | c.6816G>T p.Q2272H | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1227331225, COSV100855485; called by muse, mutect2, varscan2
- PCNX2 | c.1411G>A p.G471R | Missense Mutation (SNP) | VAF 67/168 reads (40%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs141060055; called by muse, mutect2, varscan2
- PDCD6IP | c.2299C>T p.R767* | Nonsense Mutation (SNP) | VAF 55/152 reads (36%) | catalogued as rs1408078935; called by muse, mutect2, varscan2
- PDGFRB | c.1775C>T p.T592M | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.655); catalogued as rs771835513; called by muse, mutect2, varscan2
- PEX5L | c.1547C>T p.A516V | Missense Mutation (SNP) | VAF 46/124 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as COSV55844949, COSV55860300; called by muse, mutect2, varscan2
- PFKFB2 | c.1331C>T p.T444M | Missense Mutation (SNP) | VAF 43/116 reads (37%) | PolyPhen probably damaging (1); catalogued as COSV65547156; called by muse, mutect2, varscan2
- PGGHG | c.1927G>A p.V643M | Missense Mutation (SNP) | VAF 63/163 reads (39%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.543); catalogued as rs1232071677; called by muse, mutect2, varscan2
- PHF19 | c.1144G>A p.E382K | Missense Mutation (SNP) | VAF 98/271 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.012); catalogued as rs781520232, COSV65878707; called by muse, mutect2, varscan2
- PHF20 | c.568C>T p.R190* | Nonsense Mutation (SNP) | VAF 134/258 reads (52%) | catalogued as COSV59186928; called by muse, mutect2, varscan2
- PHLDB2 | c.400C>T p.R134W | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs147258966, COSV67309187; called by muse, mutect2, varscan2
- PHRF1 | c.3422G>A p.R1141H (on ENST00000264555 / NM_001286581.2; = p.R1140H on NM_020901.4) | Missense Mutation (SNP) | VAF 22/172 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs771237093; called by muse, mutect2, varscan2
- PIANP | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 118/316 reads (37%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.057); catalogued as rs964594946, COSV100272243, COSV57707879; called by muse, mutect2, varscan2
- PIEZO2 | c.2519C>T p.P840L | Missense Mutation (SNP) | VAF 101/298 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs529806981; called by muse, mutect2, varscan2
- PIK3AP1 | c.1816C>T p.R606W | Missense Mutation (SNP) | VAF 111/287 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1255769798, COSV59531777; called by muse, mutect2, varscan2
- PIK3R6 | c.820C>T p.R274W | Missense Mutation (SNP) | VAF 60/142 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.659); catalogued as rs771646325; called by muse, mutect2, varscan2
- PIP5K1C | c.902C>T p.T301M | Missense Mutation (SNP) | VAF 13/285 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1437749484; called by muse, mutect2
- PITHD1 | c.541C>T p.R181* | Nonsense Mutation (SNP) | VAF 47/133 reads (35%) | catalogued as rs772020023, COSV55755749; called by muse, mutect2, varscan2
- PITRM1 | c.1594G>A p.G532R | Missense Mutation (SNP) | VAF 76/193 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs760990512, COSV56534660; called by muse, mutect2, varscan2
- PKD1 | c.5839G>A p.V1947M | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.68); PolyPhen benign (0.063); catalogued as rs1006776715; called by muse, mutect2, varscan2
- PKD1 | c.4010C>T p.T1337M | Missense Mutation (SNP) | VAF 219/607 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.75); catalogued as rs370569512; called by muse, mutect2, varscan2
- PKN3 | c.2506G>A p.V836M | Missense Mutation (SNP) | VAF 24/404 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as rs757025045, COSV52578238; called by muse, mutect2
- PLAAT4 | c.412G>A p.G138S | Missense Mutation (SNP) | VAF 17/172 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.21); catalogued as rs565409700, COSV55373465; called by muse, varscan2
- PLCD1 | c.1883G>A p.R628Q | Missense Mutation (SNP) | VAF 232/573 reads (40%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs372093444; called by muse, mutect2, varscan2
- PLEC | c.8728G>A p.A2910T (on ENST00000322810 / NM_201380.4; = p.A2800T on NM_000445.5) | Missense Mutation (SNP) | VAF 49/169 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs200683827; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEC | c.6307G>A p.E2103K (on ENST00000322810 / NM_201380.4; = p.E1993K on NM_000445.5) | Missense Mutation (SNP) | VAF 39/404 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs782167428; called by muse, mutect2
- PLEC | c.3938G>A p.R1313H (on ENST00000322810 / NM_201380.4; = p.R1203H on NM_000445.5) | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.011); catalogued as rs782533009, COSV100509457; called by muse, mutect2
- PLEKHA7 | c.2138G>A p.R713Q | Missense Mutation (SNP) | VAF 77/244 reads (32%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.859); catalogued as rs775992995, COSV100850090; called by muse, mutect2, varscan2
- PLEKHH3 | c.574del p.V192Wfs*6 | Frame Shift Del (DEL) | VAF 49/134 reads (37%) | catalogued as rs778393033; called by mutect2, pindel, varscan2
- PLXNA3 | c.2183G>A p.R728Q | Missense Mutation (SNP) | VAF 110/319 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.409); catalogued as rs782812977; called by muse, mutect2, varscan2
- PLXNB1 | c.334G>A p.G112R | Missense Mutation (SNP) | VAF 81/195 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1211728871; called by muse, mutect2, varscan2
- PLXNB2 | c.3733G>A p.V1245M | Missense Mutation (SNP) | VAF 85/235 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63780015; called by muse, mutect2, varscan2
- PMPCA | c.170C>T p.A57V | Missense Mutation (SNP) | VAF 46/513 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.566); catalogued as rs778953110; called by muse, mutect2
- PMPCA | c.850G>A p.V284M | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.047); catalogued as rs374905438, COSV65508853; called by muse, mutect2, varscan2
- POLG | c.3583A>G p.M1195V | Missense Mutation (SNP) | VAF 134/384 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as rs764233623, COSV51523513; called by muse, mutect2, varscan2
- POLR2B | c.3421C>T p.R1141C | Missense Mutation (SNP) | VAF 47/125 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs756916783, COSV55272321; called by muse, mutect2, varscan2
- POM121 | c.3725G>A p.R1242Q (on ENST00000434423; = p.R977Q on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs782277773, COSV57514846; called by muse, mutect2, varscan2
- PPFIA2 | c.1916C>A p.S639Y | Missense Mutation (SNP) | VAF 39/376 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100331411; called by muse, mutect2
- PPM1M | c.257G>A p.R86Q (on ENST00000296487; = p.R247Q on NM_144641.4) | Missense Mutation (SNP) | VAF 37/326 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.146); catalogued as rs201187447, COSV56599396; called by muse, mutect2, varscan2
- PPP1R3F | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV50019331; called by muse, mutect2
- PPP1R3G | c.1030G>A p.G344S | Missense Mutation (SNP) | VAF 50/138 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs750552708; called by muse, varscan2
- PPP2R2B | c.446G>A p.R149Q (on ENST00000394409; = p.R215Q on NM_181674.2) | Missense Mutation (SNP) | VAF 49/132 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs756415160, CM1410667, COSV60765117; called by muse, mutect2, varscan2
- PRAG1 | c.3214C>A p.P1072T | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.022); catalogued as rs764840780; called by muse, mutect2, varscan2
- PRKCSH | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 46/510 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs779781221; called by muse, mutect2
- PRKDC | c.9377T>C p.L3126P | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as rs551424651; called by muse, varscan2
- PROM1 | c.2296G>A p.A766T | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.646); catalogued as COSV71699231; called by muse, mutect2, varscan2
- PRR3 | c.296G>A p.R99H | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs1336538964, COSV64835163; called by muse, mutect2
- PSAP | c.1453G>A p.A485T | Missense Mutation (SNP) | VAF 124/357 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.272); catalogued as rs1313523627; called by muse, mutect2, varscan2
- PSMB2 | c.253C>T p.R85C | Missense Mutation (SNP) | VAF 55/134 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368316488, COSV100951597; called by muse, mutect2, varscan2
- PSME4 | c.949G>A p.A317T | Missense Mutation (SNP) | VAF 54/144 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.436); catalogued as COSV101122614; called by muse, varscan2
- PTK2B | c.2155C>T p.R719* | Nonsense Mutation (SNP) | VAF 83/225 reads (37%) | catalogued as COSV57763941; called by muse, mutect2, varscan2
- PTPRH | c.821C>T p.T274M | Missense Mutation (SNP) | VAF 59/145 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.091); catalogued as rs148343769; called by muse, mutect2, varscan2
- PTPRM | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 78/244 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs781449581; called by muse, mutect2, varscan2
- PTPRS | c.5143A>G p.M1715V | Missense Mutation (SNP) | VAF 72/230 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.183); catalogued as rs753283232; called by muse, mutect2, varscan2
- PTPRS | c.4262G>A p.R1421H | Missense Mutation (SNP) | VAF 20/266 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1420232605; called by muse, mutect2
- PXDN | c.4060C>T p.R1354W | Missense Mutation (SNP) | VAF 23/178 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.394); catalogued as rs565398993, COSV53230056; called by muse, mutect2, varscan2
- QSOX1 | c.2074C>T p.R692W | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.424); catalogued as rs141474961; called by muse, mutect2, varscan2
- RAB11FIP4 | c.1367G>A p.R456H | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.194); catalogued as rs369114444; called by muse, mutect2
- RAPSN | c.844C>T p.R282C | Missense Mutation (SNP) | VAF 52/385 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as rs751845474, COSV54085212; called by muse, mutect2, varscan2
- RASA4B | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 61/383 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.89); catalogued as rs777053897; called by muse, mutect2, varscan2
- RBFOX2 | c.311C>T p.P104L (on ENST00000438146 / NM_001349995.2; = p.P34L on NM_014309.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 142/436 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs140838970; called by muse, mutect2, varscan2
- RBM15B | c.1840C>T p.R614W | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs1297592395; called by muse, mutect2, varscan2
- RBM33 | c.621A>T p.E207D | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.99); catalogued as rs768319432, COSV55295467; called by muse, mutect2
- RBM42 | c.14G>T p.G5V | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.617); catalogued as rs1011313332; called by muse, mutect2
- RBM6 | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 69/172 reads (40%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as rs761561896, COSV99804894; called by muse, mutect2, varscan2
- RBMXL3 | c.3151G>A p.G1051R | Missense Mutation (SNP) | VAF 82/261 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as rs782185363, COSV57761598; called by muse, mutect2
- RBSN | c.1516G>A p.E506K | Missense Mutation (SNP) | VAF 100/248 reads (40%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.057); catalogued as rs776101358, COSV53794669; called by muse, mutect2, varscan2
- RELL1 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs1045482604; called by muse, mutect2
- RELT | c.866C>T p.S289L | Missense Mutation (SNP) | VAF 129/341 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.251); catalogued as rs371610657, COSV50362393; called by muse, mutect2, varscan2
- REST | c.1732del p.S578Vfs*7 | Frame Shift Del (DEL) | VAF 24/94 reads (26%) | catalogued as rs1199978831; called by mutect2, varscan2
- RET | c.1538C>T p.A513V | Missense Mutation (SNP) | VAF 44/458 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs149238501, COSV60688566, COSV60711451; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- REXO5 | c.1859G>A p.R620H | Missense Mutation (SNP) | VAF 126/379 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.092); catalogued as rs761648007, COSV54473096; called by muse, mutect2, varscan2
- RFLNA | c.478C>T p.R160C (on ENST00000546355 / NM_001365156.1; = p.R79C on NM_181709.4) | Missense Mutation (SNP) | VAF 163/446 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs763677847; called by muse, mutect2, varscan2
- RFPL2 | c.626G>A p.R209Q | Missense Mutation (SNP) | VAF 40/153 reads (26%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.502); catalogued as rs770071733, COSV50716765, COSV99964177; called by muse, mutect2, varscan2
- RFX5 | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 109/298 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.798); catalogued as rs774928260, COSV51841740; called by muse, mutect2, varscan2
- RGS18 | c.643C>T p.R215* | Nonsense Mutation (SNP) | VAF 66/236 reads (28%) | catalogued as rs868020301, COSV100817696, COSV66507610; called by muse, mutect2, varscan2
- RIN1 | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs151065096; called by muse, mutect2, varscan2
- RIPK4 | c.790C>T p.R264W | Missense Mutation (SNP) | VAF 112/312 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs139607246; called by muse, mutect2, varscan2
- RIPOR3 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as rs1271751658, COSV50391664; called by muse, mutect2, varscan2
- RNASEH1 | c.364G>A p.V122M | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs201353590; called by muse, mutect2, varscan2
- RNF112 | c.1762G>A p.V588M | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as rs1437341261; called by muse, mutect2, varscan2
- RNF115 | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 32/350 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs782618550, COSV100991962; called by muse, mutect2
- RNF121 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs558215963, COSV62316820; called by mutect2, varscan2
- RNF157 | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 60/160 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768402451, COSV99486730; called by muse, mutect2, varscan2
- RNF20 | c.2260C>T p.R754W | Missense Mutation (SNP) | VAF 103/275 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66660493; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 55/160 reads (34%) | catalogued as rs755128667, COSV68457540; called by mutect2, varscan2
- ROM1 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 157/337 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs1248108625; called by muse, mutect2, varscan2
- ROPN1L | c.475G>A p.G159R | Missense Mutation (SNP) | VAF 72/180 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775309425, COSV99928814; called by muse, mutect2, varscan2
- RPL22 | c.214G>A p.V72M | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV52379371; called by muse, mutect2, varscan2
- RPS6KA1 | c.967A>G p.T323A | Missense Mutation (SNP) | VAF 65/186 reads (35%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.664); catalogued as rs879121946; called by muse, mutect2, varscan2
- RPS6KA4 | c.859G>A p.A287T | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs367990117, COSV53701537; called by muse, mutect2, varscan2
- RSPH14 | c.772G>A p.A258T | Missense Mutation (SNP) | VAF 109/229 reads (48%) | SIFT tolerated (0.32); PolyPhen benign (0.095); catalogued as rs1243181000, COSV53272147; called by muse, mutect2, varscan2
- RYR3 | c.8111G>A p.R2704Q (on ENST00000389232; = p.R2705Q on NM_001036.6) | Missense Mutation (SNP) | VAF 72/168 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.772); catalogued as rs759749942, COSV101214816, COSV66787150; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR3 | c.13607G>A p.R4536H (on ENST00000389232; = p.R4537H on NM_001036.6) | Missense Mutation (SNP) | VAF 59/130 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1026263049; called by muse, mutect2, varscan2
- SALL3 | c.1795G>A p.V599I | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs750854739; called by muse, mutect2, varscan2
- SAPCD2 | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as rs575301571; called by muse, mutect2, varscan2
- SART1 | c.2153G>A p.R718Q | Missense Mutation (SNP) | VAF 82/206 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs868498844, COSV56710796; called by muse, mutect2, varscan2
- SASH1 | c.3088A>G p.T1030A | Missense Mutation (SNP) | VAF 59/166 reads (36%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as COSV66566553; called by muse, mutect2, varscan2
- SBF2 | c.5468G>A p.R1823H | Missense Mutation (SNP) | VAF 154/447 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369992460; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SBNO2 | c.3088G>A p.G1030R | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs1568550021; called by muse, mutect2, varscan2
- SBNO2 | c.2912G>A p.R971H | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100684506; called by muse, mutect2, varscan2
- SCARA3 | c.1240C>T p.R414W | Missense Mutation (SNP) | VAF 86/253 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.402); catalogued as rs376680064; called by muse, mutect2, varscan2
- SCYL1 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs371041571; called by muse, mutect2, varscan2
- SDCBP2 | c.668G>A p.R223H (on ENST00000339987 / NM_001199784.1; = p.R138H on NM_015685.5) | Missense Mutation (SNP) | VAF 82/293 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs767943587; called by muse, mutect2, varscan2
- SDK1 | c.5756C>T p.T1919M | Missense Mutation (SNP) | VAF 100/252 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs61743123; called by muse, varscan2
- SDK2 | c.5116G>A p.A1706T | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1314052840, COSV66185623; called by muse, mutect2, varscan2
- SEC14L6 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 72/176 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1049020865, COSV67857141; called by muse, mutect2, varscan2
- SELENOM | c.280-8C>T | Splice Region (SNP) | VAF 91/239 reads (38%) | catalogued as rs368373313; called by muse, mutect2, varscan2
- SERTAD2 | c.695C>T p.T232M | Missense Mutation (SNP) | VAF 121/365 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs778929323, COSV57641115; called by muse, mutect2, varscan2
- SETBP1 | c.2062G>A p.V688I | Missense Mutation (SNP) | VAF 195/575 reads (34%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs370618204; called by muse, mutect2, varscan2
- SEZ6L2 | c.1004G>A p.R335Q (on ENST00000308713 / NM_001114099.3; = p.R265Q on NM_012410.4) | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT tolerated (0.45); PolyPhen benign (0.109); catalogued as rs556280590, COSV58103023; called by muse, mutect2, varscan2
- SGSM3 | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as rs762887007, COSV50651269; called by muse, mutect2, varscan2
- SH2B2 | c.1439G>A p.R480Q | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs370458582; called by muse, mutect2, varscan2
- SH2B3 | c.70C>T p.R24W | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs984848263, COSV57982216; called by muse, mutect2, varscan2
- SHROOM2 | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 125/350 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs201212186, COSV66607797; called by muse, mutect2, varscan2
- SHROOM3 | c.4247C>T p.T1416M | Missense Mutation (SNP) | VAF 124/341 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs745954438, COSV99934289; called by muse, mutect2, varscan2
- SHROOM4 | c.3008C>A p.P1003H | Missense Mutation (SNP) | VAF 14/314 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV99173582; called by muse, mutect2
- SIGLEC11 | c.521C>T p.T174M | Missense Mutation (SNP) | VAF 50/158 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.298); catalogued as rs747895469; called by muse, mutect2, varscan2
- SIPA1 | c.1403C>T p.T468M | Missense Mutation (SNP) | VAF 70/163 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1127381; called by muse, mutect2, varscan2
- SLAMF7 | c.97G>A p.V33I | Missense Mutation (SNP) | VAF 62/164 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as rs781511925, COSV63562853; called by muse, mutect2
- SLC14A1 | c.43A>G p.M15V | Missense Mutation (SNP) | VAF 20/213 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs1309274697; called by muse, mutect2
- SLC14A2 | c.2506G>A p.A836T | Missense Mutation (SNP) | VAF 69/162 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.274); catalogued as rs765462494, COSV54907941; called by muse, mutect2, varscan2
- SLC16A14 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54618500; called by muse, mutect2
- SLC38A7 | c.70C>T p.R24W | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs748112386; called by muse, mutect2, varscan2
- SLC39A13 | c.786+6C>T | Splice Region (SNP) | VAF 111/338 reads (33%) | catalogued as rs779162662; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- SLC4A4 | c.1321C>T p.R441W (on ENST00000264485 / NM_001098484.3; = p.R397W on NM_003759.4) | Missense Mutation (SNP) | VAF 157/438 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs530167253, COSV52625721; called by muse, mutect2, varscan2
- SLC5A10 | c.22G>A p.D8N | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs1477051831, COSV58757303; called by muse, mutect2, varscan2
- SLC5A2 | c.1111G>A p.V371M | Missense Mutation (SNP) | VAF 183/505 reads (36%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.911); catalogued as rs1168451959, COSV57892765; called by muse, mutect2, varscan2
- SLC6A16 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.11); catalogued as rs758366362, COSV60027406; called by muse, mutect2, varscan2
- SLC6A18 | c.1685T>C p.L562P | Missense Mutation (SNP) | VAF 79/197 reads (40%) | SIFT tolerated (0.65); PolyPhen benign (0.01); catalogued as COSV57250011; called by muse, mutect2, varscan2
- SLC7A2 | c.1543G>A p.G515R (on ENST00000494857 / NM_001370338.1; = p.G554R on NM_003046.6) | Missense Mutation (SNP) | VAF 53/144 reads (37%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.454); catalogued as rs371137426; called by muse, varscan2
- SLC9A2 | c.2374C>T p.R792W | Missense Mutation (SNP) | VAF 26/168 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs774494897, COSV52132917; called by muse, mutect2, varscan2
- SLFN5 | c.1234C>T p.R412C | Missense Mutation (SNP) | VAF 91/208 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs763472910, COSV55481879; called by muse, mutect2, varscan2
- SLIT1 | c.4600G>A p.A1534T | Missense Mutation (SNP) | VAF 49/149 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as rs757092109; called by muse, mutect2, varscan2
- SLIT3 | c.3391G>A p.G1131R | Missense Mutation (SNP) | VAF 52/155 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs778244564, COSV100267366, COSV60590756; called by muse, mutect2, varscan2
- SLITRK5 | c.608C>T p.T203M | Missense Mutation (SNP) | VAF 110/314 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100280151; called by muse, mutect2, varscan2
- SMCHD1 | c.5308C>T p.R1770C | Missense Mutation (SNP) | VAF 42/410 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV55263921; called by muse, mutect2
- SMO | c.1220C>T p.P407L | Missense Mutation (SNP) | VAF 11/212 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50845160; called by muse, mutect2
- SMPD4 | c.2503G>A p.G835R (on ENST00000409031 / NM_017951.4; = p.G806R on NM_017751.4) | Missense Mutation (SNP) | VAF 34/344 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as rs1170993740; called by muse, mutect2
- SNED1 | c.2030C>T p.T677M | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.198); catalogued as rs762468893, COSV60034829; called by muse, mutect2
- SNTG2 | c.1540A>G p.I514V | Missense Mutation (SNP) | VAF 9/194 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.072); catalogued as rs1403338318; called by muse, mutect2
- SNX15 | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 56/166 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.101); catalogued as rs532622026; called by muse, varscan2
- SNX18 | c.65G>A p.R22Q | Missense Mutation (SNP) | VAF 28/191 reads (15%) | SIFT tolerated (0.98); PolyPhen benign (0.195); catalogued as rs867009376; called by muse, mutect2, varscan2
- SOAT2 | c.1135C>T p.R379W | Missense Mutation (SNP) | VAF 60/149 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs1012396246, COSV56859358; called by muse, mutect2, varscan2
- SOSTDC1 | c.218T>C p.V73A | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as rs201667417; called by muse, mutect2, varscan2
- SOX6 | c.2077C>T p.R693* (on ENST00000528429 / NM_001145819.2; = p.R666* on NM_017508.3) | Nonsense Mutation (SNP) | VAF 185/525 reads (35%) | catalogued as COSV57042211; called by muse, mutect2, varscan2
- SOX6 | c.1322C>T p.T441M (on ENST00000528429 / NM_001145819.2; = p.T400M on NM_017508.3) | Missense Mutation (SNP) | VAF 86/252 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs756375984, COSV57049980; called by muse, mutect2, varscan2
- SP6 | c.1096C>T p.R366C | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs1162204801; called by muse, mutect2
- SPATA13 | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs762897184; called by muse, mutect2
- SPEN | c.8221G>A p.V2741I | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.27); catalogued as rs559925121, COSV65362468, COSV65363429; called by muse, mutect2
- SPTB | c.4375C>T p.R1459W | Missense Mutation (SNP) | VAF 143/433 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs780155773; called by muse, mutect2, varscan2
- SPTBN2 | c.6554G>A p.R2185Q | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT tolerated (0.32); PolyPhen benign (0.069); catalogued as rs199806599; called by muse, mutect2, varscan2
- SREBF1 | c.710C>T p.P237L | Missense Mutation (SNP) | VAF 94/257 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs528968412; called by muse, mutect2, varscan2
- SRPK3 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 54/127 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs376752231; called by muse, mutect2, varscan2
- SSC5D | c.2533G>A p.E845K | Missense Mutation (SNP) | VAF 16/309 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1447466792; called by muse, mutect2
- SSRP1 | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV53480068; called by muse, mutect2, varscan2
- ST6GAL1 | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 76/195 reads (39%) | PolyPhen probably damaging (0.997); catalogued as rs770609191; called by muse, mutect2, varscan2
- STAP2 | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 111/304 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.17); catalogued as rs1369072695; called by muse, mutect2, varscan2
- STARD13 | c.812C>T p.A271V (on ENST00000336934 / NM_001243476.3; = p.A153V on NM_052851.3) | Missense Mutation (SNP) | VAF 66/374 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV55230852; called by muse, varscan2
- STARD6 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as rs374944431; called by muse, mutect2, varscan2
- STK32C | c.1119+1G>A p.X373_splice | Splice Site (SNP) | VAF 17/162 reads (10%) | catalogued as rs781197951, COSV53841056; called by muse, mutect2, varscan2
- STOX1 | c.509C>T p.T170M | Missense Mutation (SNP) | VAF 94/266 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.24); catalogued as rs537995029, COSV53819146; called by muse, mutect2, varscan2
- STX18 | c.812C>T p.T271M | Missense Mutation (SNP) | VAF 100/312 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as rs781259237, COSV60373452; called by muse, mutect2, varscan2
- SUDS3 | c.556C>T p.R186W | Missense Mutation (SNP) | VAF 79/220 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV64348866; called by muse, mutect2, varscan2
- SUN2 | c.1012C>T p.R338C | Missense Mutation (SNP) | VAF 51/112 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1301677505, COSV53304973; called by muse, mutect2, varscan2
- SVIL | c.4141C>T p.Q1381* (on ENST00000355867 / NM_021738.3; = p.Q955* on NM_003174.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 26/334 reads (8%) | catalogued as rs1166271687; called by muse, mutect2
- SYCP2 | c.2362del p.M788* | Frame Shift Del (DEL) | VAF 16/44 reads (36%) | catalogued as rs570102997; called by mutect2, varscan2
- SYNE1 | c.18620C>T p.T6207M (on ENST00000367255 / NM_182961.4; = p.T6136M on NM_033071.3) | Missense Mutation (SNP) | VAF 204/591 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as rs373188583; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYT5 | c.470G>A p.R157Q | Missense Mutation (SNP) | VAF 117/316 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as rs1198311817, COSV62830121; called by muse, mutect2, varscan2
- TACC3 | c.709C>T p.R237W | Missense Mutation (SNP) | VAF 28/259 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.657); catalogued as rs1285677760, COSV100508938; called by muse, mutect2, varscan2
- TANC2 | c.2882G>A p.R961Q | Missense Mutation (SNP) | VAF 25/327 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs374131489, COSV101267693; called by muse, mutect2
- TBX15 | c.1396G>A p.G466S (on ENST00000369429 / NM_001330677.2; = p.G360S on NM_152380.3) | Missense Mutation (SNP) | VAF 155/407 reads (38%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as rs370477009, COSV99253940; called by muse, mutect2, varscan2
- TBX18 | c.985C>T p.R329* | Nonsense Mutation (SNP) | VAF 72/228 reads (32%) | catalogued as rs202211205; called by muse, mutect2, varscan2
- TBX22 | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 54/544 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs781388378; called by muse, mutect2
- TBX5 | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 75/211 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs776705102; called by muse, mutect2, varscan2
- TCEAL6 | c.283C>T p.R95W | Missense Mutation (SNP) | VAF 147/339 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.043); catalogued as COSV65654311; called by muse, mutect2, varscan2
- TCF20 | c.5371C>T p.R1791C | Missense Mutation (SNP) | VAF 11/250 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1429923286, COSV59495764; called by muse, mutect2
- TEAD1 | c.1016C>T p.T339M | Missense Mutation (SNP) | VAF 123/329 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs776134890; called by muse, mutect2, varscan2
- TEDC1 | c.911G>A p.R304H (on ENST00000392523 / NM_001367178.1; = p.R235H on NM_001134875.1) | Missense Mutation (SNP) | VAF 164/412 reads (40%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs150970762; called by muse, mutect2, varscan2
- TEX10 | c.1559G>A p.R520Q | Missense Mutation (SNP) | VAF 75/243 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs781531256, COSV100887994; called by muse, mutect2, varscan2
- TEX55 | c.778C>T p.R260C | Missense Mutation (SNP) | VAF 57/175 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); catalogued as rs758956113, COSV55210774; called by muse, mutect2, varscan2
- TFF2 | c.127G>A p.G43S | Missense Mutation (SNP) | VAF 79/227 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1348103589, COSV52296846; called by muse, mutect2, varscan2
- TFR2 | c.1389C>T p.N463= | Splice Region (SNP) | VAF 192/553 reads (35%) | catalogued as rs780133884, COSV56155659; called by muse, mutect2, varscan2
- TG | c.2816C>T p.T939M | Missense Mutation (SNP) | VAF 136/369 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as rs1158331818, COSV55093883; called by muse, mutect2, varscan2
- THAP7 | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 92/305 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs773098122, COSV53146828; called by muse, mutect2, varscan2
- THBS2 | c.427G>A p.G143S | Missense Mutation (SNP) | VAF 90/266 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.359); catalogued as rs558980944, COSV64681525, COSV64681997; called by muse, mutect2, varscan2
- THOP1 | c.139G>A p.V47M | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.733); catalogued as rs145473951; called by muse, mutect2, varscan2
- TIAM1 | c.2065C>T p.R689* | Nonsense Mutation (SNP) | VAF 63/154 reads (41%) | catalogued as rs1314285809, COSV54546722; called by muse, mutect2, varscan2
- TIAM2 | c.227C>T p.S76L | Missense Mutation (SNP) | VAF 162/470 reads (34%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.121); catalogued as rs746067347; called by muse, mutect2, varscan2
- TKFC | c.1052G>A p.R351Q | Missense Mutation (SNP) | VAF 43/135 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.107); catalogued as rs765652741, COSV53651280; called by muse, mutect2, varscan2
- TKT | c.197C>T p.P66L | Missense Mutation (SNP) | VAF 111/313 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as rs906317096; called by muse, mutect2, varscan2
- TLE1 | c.1061C>T p.A354V | Missense Mutation (SNP) | VAF 48/144 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as rs770279950; called by muse, mutect2, varscan2
- TMC2 | c.1829G>A p.R610Q | Missense Mutation (SNP) | VAF 80/302 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371520403; called by muse, mutect2, varscan2
- TMED8 | c.862G>A p.V288M | Missense Mutation (SNP) | VAF 24/326 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1198145237; called by muse, mutect2
- TMEM79 | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 143/406 reads (35%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.781); catalogued as COSV55295199; called by muse, mutect2, varscan2
- TMEM98 | c.601C>T p.R201* | Nonsense Mutation (SNP) | VAF 113/319 reads (35%) | catalogued as rs756215423; called by muse, mutect2, varscan2
- TMPRSS11E | c.1240C>T p.R414W | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771409177, COSV100542549; called by muse, mutect2, varscan2
- TMPRSS13 | c.1655C>A p.P552H | Missense Mutation (SNP) | VAF 19/542 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.043); catalogued as COSV70626395; called by muse, mutect2
- TNFRSF11A | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 72/217 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.47); catalogued as rs201358688; called by muse, mutect2, varscan2
- TNIP1 | c.1063G>C p.E355Q | Missense Mutation (SNP) | VAF 55/214 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.685); catalogued as COSV100161309, COSV100161318; called by muse, mutect2, varscan2
- TNKS1BP1 | c.3107C>T p.P1036L | Missense Mutation (SNP) | VAF 93/240 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.042); catalogued as rs747045370; called by muse, mutect2, varscan2
- TNMD | c.833G>A p.R278H | Missense Mutation (SNP) | VAF 102/296 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as rs745722707, COSV100887852; called by muse, mutect2, varscan2
- TNRC18 | c.8162C>T p.T2721M | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.039); catalogued as rs751841376; called by muse, mutect2, varscan2
- TONSL | c.1505C>T p.P502L | Missense Mutation (SNP) | VAF 125/321 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs557438514, COSV101340127, COSV101340256; called by muse, mutect2, varscan2
- TPCN2 | c.1714G>A p.V572I | Missense Mutation (SNP) | VAF 71/209 reads (34%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as rs140550021; called by muse, mutect2, varscan2
- TRANK1 | c.5704C>T p.R1902W | Missense Mutation (SNP) | VAF 99/232 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs762592770, COSV100085235; called by muse, mutect2, varscan2
- TRAPPC13 | c.157G>A p.V53I | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs370490160; called by muse, mutect2, varscan2
- TRIM7 | c.1181C>T p.S394L | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs879262053; called by muse, mutect2, varscan2
- TRMT61A | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 126/309 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs376660789, COSV54569051; called by muse, mutect2, varscan2
- TRPM4 | c.2864G>A p.R955Q | Missense Mutation (SNP) | VAF 64/156 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV99419533; called by muse, mutect2, varscan2
- TSC1 | c.3080G>A p.R1027Q | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.715); catalogued as rs796053461, COSV53767202; ClinVar: uncertain significance / likely benign; called by muse, varscan2
- TSPAN10 | c.919G>A p.A307T (on ENST00000574882 / NM_001290212.1; = p.A269T on NM_031945.4) | Missense Mutation (SNP) | VAF 17/448 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.244); catalogued as COSV58507233; called by muse, mutect2
- TSPYL1 | c.368A>G p.K123R | Missense Mutation (SNP) | VAF 158/456 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1034648999, COSV63994114; called by muse, varscan2
- TTC7B | c.415C>T p.R139W | Missense Mutation (SNP) | VAF 52/174 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs1396421458, COSV60627229; called by muse, mutect2, varscan2
- TTF2 | c.2926G>A p.G976S | Missense Mutation (SNP) | VAF 66/153 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750943353; called by muse, mutect2, varscan2
- TTK | c.2560del p.R854Gfs*39 | Frame Shift Del (DEL) | VAF 27/76 reads (36%) | catalogued as rs763254614; called by mutect2, varscan2
- TTN | c.52168G>T p.G17390* (on ENST00000591111; = p.G9966* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 75/227 reads (33%) | catalogued as COSV59978988; called by muse, mutect2, varscan2
- TUBB1 | c.926G>A p.R309H | Missense Mutation (SNP) | VAF 174/333 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs776524370, COSV53888228; called by muse, mutect2, varscan2
- TUBB4A | c.436G>A p.G146R | Missense Mutation (SNP) | VAF 129/367 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.995); catalogued as rs796738621, COSV51167425; called by muse, mutect2, varscan2
- TUBGCP3 | c.1841G>A p.S614N | Missense Mutation (SNP) | VAF 79/173 reads (46%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as rs756042724; called by muse, mutect2, varscan2
- TUSC3 | c.755G>A p.R252H | Missense Mutation (SNP) | VAF 118/285 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as rs1306297233; called by muse, varscan2
- TYK2 | c.2431G>A p.G811R | Missense Mutation (SNP) | VAF 36/232 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1250128520; called by muse, mutect2, varscan2
- UBASH3B | c.1417C>T p.R473C | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs949908246, COSV52491433; called by muse, varscan2
- UBC | c.1870G>A p.E624K | Missense Mutation (SNP) | VAF 154/446 reads (35%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.583); catalogued as rs763790896; called by muse, varscan2
- UBE3B | c.3070C>T p.R1024W | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs776429830, COSV61074792; called by muse, mutect2, varscan2
- UBR5 | c.2981G>A p.R994H | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs751155901, COSV99640828; called by muse, mutect2, varscan2
- UFL1 | c.1772C>T p.S591L | Missense Mutation (SNP) | VAF 52/151 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0.028); catalogued as rs749306296, COSV65149756; called by muse, mutect2, varscan2
- UNC13D | c.1000G>A p.V334I | Missense Mutation (SNP) | VAF 25/393 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs373019036; called by muse, mutect2
- UNC5C | c.1007G>A p.R336H | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs763344659, COSV101497886; called by muse, mutect2, varscan2
- USF3 | c.5363G>A p.R1788H | Missense Mutation (SNP) | VAF 82/249 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs201006777, COSV57072020; called by muse, mutect2, varscan2
- USP28 | c.2782A>G p.N928D | Missense Mutation (SNP) | VAF 20/190 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1157367590; called by muse, mutect2
- VPS11 | c.106G>A p.D36N (on ENST00000620429; = p.D580N on NM_021729.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 60/143 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0.194); catalogued as rs782510678, COSV56184051; called by muse, mutect2, varscan2
- VPS53 | c.1081C>T p.R361C (on ENST00000571805 / NM_001366253.2; = p.R332C on NM_018289.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1239855738, COSV52136140; called by muse, mutect2, varscan2
- VRK3 | c.1339G>A p.A447T | Missense Mutation (SNP) | VAF 34/274 reads (12%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as rs201178243; called by muse, mutect2, varscan2
- VSIG2 | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT tolerated (0.85); PolyPhen benign (0.074); catalogued as rs767545319; called by muse, mutect2
- VWC2L | c.172G>A p.G58S | Missense Mutation (SNP) | VAF 121/349 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768008280, COSV56973112; called by muse, mutect2, varscan2
- WDR27 | c.2330G>A p.R777H | Missense Mutation (SNP) | VAF 78/208 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs377120387; called by muse, mutect2, varscan2
- WDR27 | c.1414G>A p.V472I | Missense Mutation (SNP) | VAF 78/185 reads (42%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as rs371086301; called by muse, mutect2, varscan2
- WDR82 | c.577C>T p.R193* | Nonsense Mutation (SNP) | VAF 65/162 reads (40%) | catalogued as COSV56602584; called by muse, mutect2, varscan2
- WEE2 | c.110C>T p.S37L | Missense Mutation (SNP) | VAF 120/308 reads (39%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs746485209, COSV66878318; called by muse, mutect2, varscan2
- WNK2 | c.4198G>A p.A1400T (on ENST00000297954 / NM_001282394.1; = p.A1363T on NM_006648.3) | Missense Mutation (SNP) | VAF 15/229 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.134); catalogued as COSV52942172; called by muse, mutect2
- WNK2 | c.6869C>T p.A2290V | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs538274602, COSV99943573; called by muse, mutect2, varscan2
- WNK4 | c.1169C>T p.S390L | Missense Mutation (SNP) | VAF 155/423 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99519349; called by muse, mutect2, varscan2
- WNT3 | c.779G>A p.R260Q | Missense Mutation (SNP) | VAF 95/226 reads (42%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.979); catalogued as rs1488424377; called by muse, mutect2, varscan2
- WRAP73 | c.1208C>T p.A403V | Missense Mutation (SNP) | VAF 114/282 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as rs367621103; called by muse, mutect2, varscan2
- WRN | c.3973G>A p.V1325I | Missense Mutation (SNP) | VAF 118/332 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756510312; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WWC3 | c.896G>A p.R299Q | Missense Mutation (SNP) | VAF 156/390 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0.238); catalogued as rs774287529; called by muse, mutect2, varscan2
- XAB2 | c.1093G>A p.A365T | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs375722248; called by muse, mutect2, varscan2
- XIAP | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 111/331 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.437); catalogued as rs368511826, COSV63022134; called by muse, mutect2, varscan2
- XPO7 | c.2900G>A p.R967H | Missense Mutation (SNP) | VAF 72/185 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs375897041; called by muse, mutect2, varscan2
- YTHDC1 | c.1009G>A p.V337I | Missense Mutation (SNP) | VAF 48/164 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.071); catalogued as rs771726851, COSV60010526; called by muse, mutect2, varscan2
- ZBED4 | c.3001C>T p.R1001W | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757194437, COSV99351880; called by muse, mutect2, varscan2
- ZBTB21 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 113/316 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs753169498; called by muse, mutect2
- ZFHX4 | c.8698G>A p.E2900K | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1203436770, COSV50810800, COSV99255019; called by muse, mutect2, varscan2
- ZKSCAN2 | c.1105C>T p.R369* | Nonsense Mutation (SNP) | VAF 92/204 reads (45%) | catalogued as rs1354379366, COSV100047713; called by muse, mutect2, varscan2
- ZKSCAN7 | c.1685G>A p.R562Q | Missense Mutation (SNP) | VAF 34/293 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.038); catalogued as rs574206888; called by muse, mutect2, varscan2
- ZNF106 | c.2263C>T p.R755C | Missense Mutation (SNP) | VAF 90/203 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1300074273; called by muse, mutect2, varscan2
- ZNF16 | c.1610G>A p.R537Q | Missense Mutation (SNP) | VAF 114/305 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs751615367; called by muse, mutect2, varscan2
- ZNF225 | c.484G>A p.V162I | Missense Mutation (SNP) | VAF 79/185 reads (43%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs753484957; called by muse, mutect2, varscan2
- ZNF234 | c.469T>A p.F157I | Missense Mutation (SNP) | VAF 64/163 reads (39%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.993); catalogued as rs778778540; called by muse, mutect2, varscan2
- ZNF382 | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 44/178 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs767122431; called by muse, mutect2, varscan2
- ZNF407 | c.5666C>T p.T1889M | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs553117551, COSV55254908; called by muse, mutect2, varscan2
- ZNF516 | c.1094C>T p.T365M | Missense Mutation (SNP) | VAF 40/411 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.096); catalogued as rs930040861; called by muse, mutect2
- ZNF536 | c.1523C>T p.A508V | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1223055764, COSV62831990, COSV62835027; called by muse, mutect2, varscan2
- ZNF564 | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 105/256 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs554040776, COSV59435921; called by muse, mutect2, varscan2
- ZNF618 | c.316G>A p.V106I | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.381); catalogued as rs1358629363, COSV55930727; called by muse, mutect2, varscan2
- ZNF629 | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.987); catalogued as rs1484415050; called by muse, mutect2
- ZNF649 | c.916G>A p.V306I | Missense Mutation (SNP) | VAF 90/257 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761477266, COSV56815984; called by muse, mutect2, varscan2
- ZNF665 | c.94G>A p.D32N (on ENST00000600412; = p.D97N on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 73/172 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.183); catalogued as rs753439552, COSV67217416, COSV67217556; called by muse, mutect2, varscan2
- ZNF674 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs756871981; called by muse, mutect2, varscan2
- ZNF682 | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 47/162 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201103446; called by muse, mutect2, varscan2
- ZNF710 | c.1511C>T p.A504V | Missense Mutation (SNP) | VAF 58/146 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs149111907; called by muse, mutect2, varscan2
- ZNF747 | c.380C>T p.A127V | Missense Mutation (SNP) | VAF 57/142 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as rs1015390934; called by muse, mutect2, varscan2
- ZNF776 | c.124G>A p.V42M | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57815741; called by muse, mutect2, varscan2
- ZNF804B | c.587G>A p.R196H | Missense Mutation (SNP) | VAF 87/223 reads (39%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs1402099743, COSV60843906; called by muse, mutect2, varscan2
- ZNF831 | c.3415C>T p.R1139W | Missense Mutation (SNP) | VAF 75/147 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as rs745689615; called by muse, mutect2, varscan2
- ZNF850 | c.2075G>A p.R692Q | Missense Mutation (SNP) | VAF 81/174 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs748702950, COSV101648599; called by muse, mutect2, varscan2
- ZSCAN10 | c.1279G>A p.G427S (on ENST00000252463; = p.G482S on NM_032805.3) | Missense Mutation (SNP) | VAF 84/244 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs1322177194, COSV52971294; called by muse, mutect2, varscan2
- ABCC2 | c.4325G>T p.R1442M | Missense Mutation (SNP) | VAF 13/372 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- AC008397.2 | c.1111G>A p.A371T | Missense Mutation (SNP) | VAF 28/278 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.05); called by muse, mutect2
972 further variants in this file (341 protein-altering or splice-affecting, 430 silent, 201 other) are not listed here.
